Somatic mutation profile of tumor specimen TCGA-BR-8382-01A (aliquot TCGA-BR-8382-01A-11D-2394-08) from TCGA case TCGA-BR-8382, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Gastric antrum; AJCC pathologic stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 67.7 years (24,737 days).
Specimen TCGA-BR-8382-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 26e52b1a-fd6d-455f-b797-9d7b140a149d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BR-8382-10A (Blood Derived Normal), aliquot TCGA-BR-8382-10A-01D-2394-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8eeece83-5a07-4e74-a00a-19d925a9448f

The open-access MAF lists 1,088 somatic variants for this specimen: 834 protein-altering or splice-affecting, 229 silent, 25 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 569, Silent 229, Frame Shift Del 187, Frame Shift Ins 26, Nonsense Mutation 25, Intron 12, Splice Site 12, In Frame Del 7, Splice Region 7, 3'UTR 4, RNA 4, 5'Flank 2.

Variants (750 of 1,088; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATP7B | c.3188C>T p.A1063V | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs587783309, CM992821, COSV54435095, COSV54440441; ClinVar: likely pathogenic / benign; called by muse, mutect2, varscan2
- DLG3 | c.1092dup p.T365Hfs*13 | Frame Shift Ins (INS) | VAF 6/52 reads (12%) | catalogued as rs398122846; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- EP300 | c.4397G>T p.W1466L | Missense Mutation (SNP) | VAF 17/78 reads (22%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.017); catalogued as COSV54329712, COSV54343301, COSV54343868; called by muse, mutect2, varscan2
- ERBB3 | c.310G>A p.V104M | Missense Mutation (SNP) | VAF 25/160 reads (16%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen possibly damaging (0.64); catalogued as rs1057519893, COSV57246387, COSV57246465, COSV57253558; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- KANSL1 | c.779del p.G260Vfs*19 | Frame Shift Del (DEL) | VAF 12/77 reads (16%) | catalogued as rs748018297; ClinVar: uncertain significance / pathogenic; called by mutect2, pindel, varscan2
- KMT2B | c.521dup p.T176Dfs*8 | Frame Shift Ins (INS) | VAF 24/152 reads (16%) | catalogued as rs763183959; ClinVar: pathogenic; called by mutect2, varscan2
- KMT2D | c.1966del p.L656Cfs*274 | Frame Shift Del (DEL) | VAF 19/93 reads (20%) | catalogued as rs886042284; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- MSH3 | c.1148del p.K383Rfs*32 | Frame Shift Del (DEL) | VAF 17/99 reads (17%) | catalogued as rs587776701; ClinVar: pathogenic; called by mutect2, varscan2
- MSH6 | c.3312del p.F1104Lfs*11 | Frame Shift Del (DEL) | VAF 16/88 reads (18%) | catalogued as rs267608092; ClinVar: not provided / pathogenic; called by mutect2, pindel, varscan2
- MTHFR | c.1163G>A p.R388H | Missense Mutation (SNP) | VAF 29/202 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs769953411, COSV64878141; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PAH | c.721C>T p.R241C | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.991); catalogued as rs76687508, CM930548, COSV61018094; ClinVar: pathogenic; called by muse, mutect2, varscan2
- RAD50 | c.2165del p.K722Rfs*14 | Frame Shift Del (DEL) | VAF 12/65 reads (18%) | catalogued as rs397507178, COSV54758496; ClinVar: pathogenic; called by mutect2, varscan2
- RYR2 | c.1259G>A p.R420Q | Missense Mutation (SNP) | VAF 8/95 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.454); catalogued as rs794728721, CM097927, COSV63679796; ClinVar: pathogenic / uncertain significance; called by muse, mutect2
- SET | c.352C>T p.H118Y (on ENST00000372692 / NM_001374326.1; = p.H105Y on NM_003011.4) | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.904); catalogued as rs1564360978, COSV59003102; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TGFB2 | c.821del p.N274Tfs*10 | Frame Shift Del (DEL) | VAF 11/70 reads (16%) | catalogued as rs863223796; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- TPO | c.2421del p.C808Afs*24 | Frame Shift Del (DEL) | VAF 9/65 reads (14%) | catalogued as rs760307139, COSV100220194; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- AADACL3 | c.762del p.Q255Kfs*14 | Frame Shift Del (DEL) | VAF 22/153 reads (14%) | catalogued as rs746497630; called by mutect2, varscan2
- ABCA10 | c.2251C>A p.L751I | Missense Mutation (SNP) | VAF 17/91 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV52225538; called by muse, mutect2, varscan2
- ABCA4 | c.5329A>G p.M1777V | Missense Mutation (SNP) | VAF 26/171 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.654); catalogued as COSV64674954; called by muse, mutect2, varscan2
- ABCB1 | c.3043del p.T1015Pfs*3 | Frame Shift Del (DEL) | VAF 10/86 reads (12%) | catalogued as COSV55964223; called by mutect2, pindel, varscan2
- ABCC9 | c.4112T>C p.V1371A | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.393); catalogued as COSV53977220; called by muse, mutect2
- AC005324.2 | c.1046C>T p.A349V | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.889); catalogued as rs1461866349, COSV60887306; called by muse, mutect2, varscan2
- AC090517.4 | c.1312T>G p.F438V | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50996075, COSV50998231; called by muse, mutect2, varscan2
- ACBD3 | c.568del p.R190Gfs*43 | Frame Shift Del (DEL) | VAF 9/42 reads (21%) | catalogued as rs757016425; called by mutect2, varscan2
- ACER2 | c.542C>T p.S181L | Missense Mutation (SNP) | VAF 30/180 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.269); catalogued as rs373300481; called by muse, mutect2, varscan2
- ACVR2A | c.1310del p.K437Rfs*5 | Frame Shift Del (DEL) | VAF 11/71 reads (15%) | catalogued as rs764719749, COSV104385546; called by mutect2, varscan2
- ADAM15 | c.2205C>T p.Y735= | Splice Region (SNP) | VAF 9/80 reads (11%) | catalogued as COSV55128125; called by muse, mutect2, varscan2
- ADAM20 | c.667T>C p.S223P | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.793); catalogued as COSV56455522; called by muse, mutect2, varscan2
- ADAM29 | c.1460G>A p.C487Y | Missense Mutation (SNP) | VAF 28/119 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63665313; called by muse, mutect2, varscan2
- ADAMTS16 | c.3034G>A p.A1012T | Missense Mutation (SNP) | VAF 17/88 reads (19%) | SIFT tolerated (0.31); PolyPhen benign (0.011); catalogued as COSV56995936, COSV99943134; called by muse, mutect2, varscan2
- ADAMTS16 | c.3332C>T p.P1111L | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs763057873, COSV56995955, COSV99941372; called by muse, mutect2, varscan2
- ADAMTS18 | c.3582G>T p.W1194C | Missense Mutation (SNP) | VAF 15/81 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51418491; called by muse, mutect2, varscan2
- ADAMTS19 | c.3090G>T p.K1030N | Missense Mutation (SNP) | VAF 15/90 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.127); catalogued as COSV50762845; called by muse, mutect2, varscan2
- ADCY1 | c.1311G>T p.K437N | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.685); catalogued as COSV52037539, COSV52039184; called by muse, mutect2, varscan2
- ADGRB3 | c.687C>A p.C229* | Nonsense Mutation (SNP) | VAF 6/39 reads (15%) | catalogued as COSV101002101; called by muse, mutect2, varscan2
- ADGRG1 | c.1459C>A p.L487I | Missense Mutation (SNP) | VAF 18/139 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV65636042; called by muse, mutect2, varscan2
- ADGRG5 | c.463G>A p.V155I | Missense Mutation (SNP) | VAF 23/129 reads (18%) | SIFT tolerated (0.48); PolyPhen benign (0.061); catalogued as rs143828233; called by muse, mutect2, varscan2
- ADGRG7 | c.2314C>T p.R772C | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.609); catalogued as rs772948883, COSV56298453; called by muse, mutect2, varscan2
- ADGRL1 | c.1855-2A>C p.X619_splice (on ENST00000340736 / NM_001008701.3; = p.X614_splice on NM_014921.5) | Splice Site (SNP) | VAF 11/87 reads (13%) | catalogued as COSV61565420; called by muse, mutect2, varscan2
- ADH6 | c.758_760del p.E253del | In Frame Del (DEL) | VAF 42/290 reads (14%) | catalogued as rs1560805281; called by pindel, varscan2
- ADNP | c.3047del p.K1016Rfs*11 | Frame Shift Del (DEL) | VAF 28/92 reads (30%) | catalogued as rs761350619; called by mutect2, varscan2
- ADRA1A | c.818C>T p.T273M | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1218686921, COSV52361833; called by muse, mutect2, varscan2
- ADRB1 | c.587T>C p.M196T | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); catalogued as COSV65168090; called by muse, mutect2, varscan2
- AFAP1 | c.1744C>T p.R582W | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs766985200, COSV61796738; called by muse, mutect2, varscan2
- AGRN | c.3003del p.G1002Afs*38 | Frame Shift Del (DEL) | VAF 6/30 reads (20%) | catalogued as rs763573703; called by mutect2, varscan2
- AHNAK2 | c.11984C>T p.A3995V | Missense Mutation (SNP) | VAF 52/361 reads (14%) | SIFT tolerated (0.52); PolyPhen benign (0.163); catalogued as rs146136367, COSV60907036; called by muse, mutect2, varscan2
- AKAP14 | c.446C>T p.A149V | Missense Mutation (SNP) | VAF 15/99 reads (15%) | SIFT tolerated (0.45); PolyPhen benign (0.179); catalogued as rs769306847, COSV57630637; called by muse, mutect2, varscan2
- AKAP4 | c.796C>G p.P266A | Missense Mutation (SNP) | VAF 12/89 reads (13%) | SIFT tolerated (0.93); PolyPhen benign (0); catalogued as COSV62074856; called by muse, mutect2, varscan2
- AKAP7 | c.236del p.K79Rfs*21 | Frame Shift Del (DEL) | VAF 10/45 reads (22%) | catalogued as rs763109484, COSV100818792; called by mutect2, varscan2
- AKR7L | c.954G>T p.W318C | Missense Mutation (SNP) | VAF 16/96 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV70167680; called by muse, mutect2, varscan2
- AKT2 | c.1040G>A p.R347H | Missense Mutation (SNP) | VAF 13/97 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.36); catalogued as rs202125073, COSV60907778, COSV60908391; called by muse, mutect2, varscan2
- ALPK2 | c.5759C>T p.T1920M | Missense Mutation (SNP) | VAF 17/100 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs372914995; called by muse, mutect2, varscan2
- ANAPC1 | c.3112C>T p.R1038* | Nonsense Mutation (SNP) | VAF 9/40 reads (23%) | catalogued as rs1437191682; called by mutect2, varscan2
- ANK3 | c.7100G>A p.R2367Q | Missense Mutation (SNP) | VAF 13/89 reads (15%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.007); catalogued as rs775210756, COSV55045223; called by muse, mutect2, varscan2
- ANKMY1 | c.227C>T p.A76V | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.211); catalogued as rs769468041, COSV56040967; called by muse, mutect2
- ANKRD22 | c.139G>A p.A47T | Missense Mutation (SNP) | VAF 36/273 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1230342078, COSV64236879; called by muse, mutect2, varscan2
- ANKRD35 | c.2341G>A p.A781T | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs782724338, COSV62910890; called by muse, mutect2, varscan2
- AOC1 | c.2222del p.P741Lfs*54 | Frame Shift Del (DEL) | VAF 6/67 reads (9%) | catalogued as rs999461756; called by mutect2, pindel
- AP3B1 | c.144G>T p.K48N | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV99672699; called by muse, mutect2
- APEX2 | c.94G>A p.V32M | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.33); PolyPhen benign (0.021); catalogued as COSV100895224; called by muse, mutect2
- AQP8 | c.158G>T p.C53F | Missense Mutation (SNP) | VAF 28/291 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV54846103; called by muse, mutect2
- ARHGAP17 | c.2440del p.Q814Nfs*23 (on ENST00000289968 / NM_001006634.3; = p.Q736Nfs*23 on NM_018054.6) | Frame Shift Del (DEL) | VAF 43/255 reads (17%) | catalogued as rs773922861; called by mutect2, pindel, varscan2
- ARHGAP33 | c.3103C>A p.R1035S | Missense Mutation (SNP) | VAF 22/103 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.051); catalogued as COSV50131049; called by muse, mutect2, varscan2
- ARHGAP35 | c.3440G>A p.R1147H | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.929); catalogued as COSV68330597; called by muse, mutect2, varscan2
- ARHGAP9 | c.1468C>T p.P490S (on ENST00000393797 / NM_001319850.2; = p.P471S on NM_032496.4) | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.3); PolyPhen benign (0.021); catalogued as COSV57364187; called by muse, mutect2
- ARHGEF15 | c.1183C>A p.L395M | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV100729980; called by muse, mutect2, varscan2
- ARHGEF15 | c.1810C>T p.R604C | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs587777166, CM136400, COSV62725476; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ARID1A | c.3788C>T p.A1263V | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.024); catalogued as COSV61381737; called by muse, mutect2, varscan2
- ASTN2 | c.1651C>T p.R551C (on ENST00000313400 / NM_001365069.1; = p.R500C on NM_014010.5) | Missense Mutation (SNP) | VAF 9/81 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs776841753, COSV57773431; called by muse, mutect2, varscan2
- ASXL1 | c.166C>A p.L56I | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60112490; called by muse, mutect2, varscan2
- ATG2A | c.4841G>T p.G1614V | Missense Mutation (SNP) | VAF 21/109 reads (19%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as COSV65967420; called by muse, mutect2, varscan2
- ATP1A4 | c.276del p.T93Pfs*48 | Frame Shift Del (DEL) | VAF 22/98 reads (22%) | catalogued as rs760258351; called by mutect2, varscan2
- ATP2B3 | c.1859G>A p.R620Q | Missense Mutation (SNP) | VAF 6/102 reads (6%) | SIFT tolerated (0.26); PolyPhen benign (0.054); catalogued as rs943411634, COSV54852904; called by muse, mutect2
- ATP6V0A1 | c.1896+2T>C p.X632_splice | Splice Site (SNP) | VAF 21/104 reads (20%) | catalogued as COSV52875103; called by muse, mutect2, varscan2
- ATP6V0A4 | c.638C>T p.T213M | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs539497353, COSV59475611; called by mutect2, varscan2
- ATXN7L2 | c.1160A>G p.E387G | Missense Mutation (SNP) | VAF 23/158 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as COSV60205263; called by muse, mutect2, varscan2
- AXL | c.160C>A p.L54I | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.765); catalogued as rs765631388, COSV56570647; called by muse, mutect2
- B2M | c.285del p.D96Mfs*7 | Frame Shift Del (DEL) | VAF 14/95 reads (15%) | catalogued as COSV62562983; called by mutect2, pindel, varscan2
- BAG5 | c.974del p.N325Tfs*12 | Frame Shift Del (DEL) | VAF 15/85 reads (18%) | catalogued as rs1002009532; called by mutect2, pindel, varscan2
- BCL6B | c.1367G>A p.R456Q | Missense Mutation (SNP) | VAF 21/98 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs769964987, COSV53428480; called by muse, mutect2, varscan2
- BCL7A | c.121A>G p.T41A | Missense Mutation (SNP) | VAF 14/100 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55849387; called by muse, mutect2, varscan2
- BCL9L | c.1172G>A p.R391H | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.662); catalogued as rs761142257, COSV52686409; called by muse, mutect2, varscan2
- BDKRB1 | c.449G>A p.R150Q | Missense Mutation (SNP) | VAF 29/146 reads (20%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.861); catalogued as rs749702636, COSV53706580, COSV99388014; called by muse, mutect2, varscan2
- BICC1 | c.2392C>T p.L798F | Missense Mutation (SNP) | VAF 31/140 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.012); catalogued as COSV54064840; called by muse, mutect2, varscan2
- BICRAL | c.506C>T p.T169M | Missense Mutation (SNP) | VAF 16/152 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.657); catalogued as COSV58405926; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.139C>T p.P47S | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT tolerated, low confidence (0.76); PolyPhen benign (0.022); catalogued as COSV57280801; called by muse, mutect2, varscan2
- BMPR2 | c.1748del p.N583Tfs*44 | Frame Shift Del (DEL) | VAF 12/74 reads (16%) | catalogued as rs772920507, COSV65808737; called by mutect2, pindel, varscan2
- BMT2 | c.860C>T p.A287V | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.716); catalogued as COSV51778173; called by muse, mutect2, varscan2
- BNC2 | c.2704G>T p.D902Y | Missense Mutation (SNP) | VAF 18/130 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as COSV66169299; called by muse, mutect2, varscan2
- BRD1 | c.2317G>A p.E773K | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT tolerated (0.26); PolyPhen benign (0.048); catalogued as COSV53457173; called by muse, mutect2, varscan2
- BRINP2 | c.1733A>C p.K578T | Missense Mutation (SNP) | VAF 5/57 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.544); catalogued as COSV64178533; called by muse, mutect2
- BRSK1 | c.979G>T p.G327C | Missense Mutation (SNP) | VAF 14/93 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58666196; called by muse, mutect2, varscan2
- BTBD11 | c.1682C>T p.A561V (on ENST00000280758 / NM_001018072.2; = p.A98V on NM_001017523.2) | Missense Mutation (SNP) | VAF 29/152 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1368588123, COSV55016681; called by muse, mutect2, varscan2
- C1orf226 | c.778G>A p.D260N | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as rs767362145, COSV63395937; called by muse, mutect2, varscan2
- CA10 | c.764A>C p.K255T | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.785); catalogued as COSV53343736, COSV53357801; called by muse, varscan2
- CACNA1D | c.1255C>T p.R419W | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs371212198; called by muse, mutect2, varscan2
- CACNB4 | c.1516C>T p.R506* | Nonsense Mutation (SNP) | VAF 8/29 reads (28%) | catalogued as rs779983066, COSV52397345; called by muse, mutect2, varscan2
- CACNG8 | c.424G>A p.G142R | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54415698, COSV99554878, COSV99555036; called by muse, mutect2, varscan2
- CAMK2G | c.809C>A p.P270Q | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.999); catalogued as COSV59483309; called by muse, mutect2, varscan2
- CARS2 | c.1037G>A p.R346Q | Missense Mutation (SNP) | VAF 19/128 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0.067); catalogued as rs773315723, COSV57287231; called by muse, mutect2, varscan2
- CASZ1 | c.3964C>T p.R1322W | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs780053498, COSV59738097; called by mutect2, varscan2
- CBX6 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs757736292, COSV53321313; called by muse, mutect2, varscan2
- CBY2 | c.236G>A p.R79Q | Missense Mutation (SNP) | VAF 12/110 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.811); catalogued as rs1294168347, COSV60117217; called by muse, mutect2, varscan2
- CCAR1 | c.979C>T p.R327C | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs1323404713, COSV56268837; called by muse, varscan2
- CCDC15 | c.130G>A p.A44T | Missense Mutation (SNP) | VAF 6/89 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV61083083; called by muse, mutect2
- CCDC27 | c.1915del p.L639Cfs*8 | Frame Shift Del (DEL) | VAF 22/136 reads (16%) | catalogued as rs751021664; called by mutect2, varscan2
- CCDC40 | c.2248G>T p.G750W | Missense Mutation (SNP) | VAF 13/102 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV66476262; called by muse, mutect2, varscan2
- CCDC59 | c.296C>T p.A99V | Missense Mutation (SNP) | VAF 30/148 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV50259954, COSV50260213; called by muse, mutect2, varscan2
- CCNF | c.1747G>T p.G583C | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV99564296; called by muse, mutect2, varscan2
- CCNL2 | c.374T>C p.M125T | Missense Mutation (SNP) | VAF 12/96 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.424); catalogued as COSV61224388; called by muse, mutect2, varscan2
- CCNY | c.851C>T p.A284V | Missense Mutation (SNP) | VAF 19/88 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.094); catalogued as rs770672421, COSV55187028; called by muse, mutect2, varscan2
- CCR9 | c.593G>A p.C198Y (on ENST00000357632 / NM_031200.3; = p.C186Y on NM_006641.4) | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62940471; called by muse, mutect2, varscan2
- CCT8L2 | c.628G>A p.G210R | Missense Mutation (SNP) | VAF 17/119 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs769261313, COSV63463005, COSV63463552; called by muse, mutect2, varscan2
- CD163L1 | c.3577A>G p.S1193G | Missense Mutation (SNP) | VAF 35/170 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV58019285; called by muse, mutect2, varscan2
- CD93 | c.838del p.D280Mfs*19 | Frame Shift Del (DEL) | VAF 34/234 reads (15%) | catalogued as rs1276928429, COSV55666935; called by mutect2, varscan2
- CDC42BPG | c.1843G>A p.A615T | Missense Mutation (SNP) | VAF 24/138 reads (17%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs200332352, COSV61348159; called by muse, mutect2, varscan2
- CDC42BPG | c.761G>A p.G254D | Missense Mutation (SNP) | VAF 28/175 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61348166; called by muse, mutect2, varscan2
- CDC73 | c.954G>A p.M318I | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.742); catalogued as COSV100814078; called by muse, mutect2, varscan2
- CDH11 | c.1267C>G p.R423G | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.617); catalogued as COSV51768028; called by muse, mutect2, varscan2
- CDK5RAP2 | c.710T>C p.I237T | Missense Mutation (SNP) | VAF 13/100 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV62575755; called by muse, mutect2, varscan2
- CENPS-CORT | c.152C>T p.S51L | Missense Mutation (SNP) | VAF 24/142 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.958); catalogued as rs771382657, COSV58364242; called by muse, mutect2, varscan2
- CENPT | c.1281-2A>C p.X427_splice | Splice Site (SNP) | VAF 10/100 reads (10%) | catalogued as COSV54650738; called by muse, mutect2
- CEP20 | c.53del p.K18Rfs*4 | Frame Shift Del (DEL) | VAF 10/54 reads (19%) | catalogued as rs746479678; called by mutect2, pindel, varscan2
- CEP72 | c.646A>G p.S216G | Missense Mutation (SNP) | VAF 31/177 reads (18%) | SIFT tolerated (0.61); PolyPhen benign (0.001); catalogued as COSV53794266; called by muse, mutect2, varscan2
- CFAP46 | c.462del p.S155Afs*6 | Frame Shift Del (DEL) | VAF 24/129 reads (19%) | catalogued as rs1330842083; called by mutect2, pindel, varscan2
- CFHR2 | c.137C>A p.P46H | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); catalogued as COSV66381549; called by muse, mutect2, varscan2
- CHD3 | c.5641C>T p.R1881C (on ENST00000330494 / NM_001005273.3; = p.R1847C on NM_005852.4) | Missense Mutation (SNP) | VAF 13/109 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57877175; called by muse, mutect2, varscan2
- CHFR | c.719C>T p.A240V (on ENST00000432561 / NM_001161345.1; = p.A199V on NM_018223.2) | Missense Mutation (SNP) | VAF 20/117 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.066); catalogued as rs150995074; called by muse, mutect2, varscan2
- CHRNA3 | c.1477G>T p.G493* | Nonsense Mutation (SNP) | VAF 10/60 reads (17%) | catalogued as COSV55139239; called by muse, mutect2, varscan2
- CHRNB3 | c.242T>C p.L81P | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51496003; called by muse, mutect2, varscan2
- CHST3 | c.604G>A p.V202M | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated (0.23); PolyPhen benign (0.027); catalogued as COSV64151236; called by muse, mutect2, varscan2
- CHST8 | c.1205G>A p.R402H | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.577); catalogued as rs916046058, COSV52856983; called by muse, mutect2, varscan2
- CIC | c.404dup p.G136Rfs*8 | Frame Shift Ins (INS) | VAF 10/69 reads (14%) | catalogued as rs1384930527; called by mutect2, pindel, varscan2
- CLCA4 | c.1684G>A p.V562M | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV55369433; called by muse, mutect2, varscan2
- CLDN10 | c.50G>T p.G17V | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100176315; called by muse, mutect2, varscan2
- CLEC7A | c.346C>A p.L116I (on ENST00000304084 / NM_197947.3; = p.L70I on NM_022570.5) | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV53723030; called by muse, mutect2, varscan2
- CLIC5 | c.629T>C p.V210A (on ENST00000185206 / NM_001370649.1; = p.V51A on NM_016929.5) | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as COSV51761098; called by muse, mutect2, varscan2
- CLIP3 | c.961G>A p.G321S | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); catalogued as COSV62112903; called by muse, mutect2, varscan2
- CLMN | c.62T>C p.I21T | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.081); catalogued as COSV54184372; called by muse, mutect2
- CLPTM1 | c.1291C>A p.L431I | Missense Mutation (SNP) | VAF 25/154 reads (16%) | SIFT tolerated (0.66); PolyPhen benign (0.046); catalogued as rs1373294326, COSV61612339; called by muse, mutect2, varscan2
- CLTB | c.289A>G p.T97A | Missense Mutation (SNP) | VAF 31/192 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.338); catalogued as COSV60044897; called by muse, mutect2, varscan2
- CNGA4 | c.190G>A p.G64S | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as rs759955658, COSV56411269; called by muse, mutect2, varscan2
- CNOT1 | c.1496G>A p.R499H | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs763930906, COSV57771979; called by muse, mutect2, varscan2
- CNTNAP2 | c.2329C>T p.R777C | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs1375981068, COSV100673045, COSV62211214; called by muse, mutect2
- COBLL1 | c.2834del p.L945Cfs*12 (on ENST00000392717; = p.L907Cfs*12 on NM_014900.5) | Frame Shift Del (DEL) | VAF 10/58 reads (17%) | catalogued as rs374805044; called by mutect2, varscan2
- COG8 | c.836G>A p.R279H | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54742803; called by muse, mutect2, varscan2
- COL15A1 | c.2738G>A p.R913H | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.101); catalogued as rs376526167, COSV66646882; called by muse, mutect2, varscan2
- COL6A1 | c.43T>C p.C15R | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as COSV62614104; called by muse, mutect2, varscan2
- COL8A1 | c.2025G>T p.W675C | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.545); catalogued as COSV53737437; called by muse, mutect2, varscan2
- COQ10B | c.360T>G p.Y120* | Nonsense Mutation (SNP) | VAF 5/43 reads (12%) | catalogued as COSV55836923; called by muse, mutect2, varscan2
- CPNE5 | c.1019G>T p.G340V | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV55197838; called by muse, mutect2, varscan2
- CR2 | c.624del p.T209Hfs*10 | Frame Shift Del (DEL) | VAF 19/133 reads (14%) | catalogued as rs747832403; called by mutect2, pindel, varscan2
- CRYBG2 | c.1178del p.K393Rfs*16 | Frame Shift Del (DEL) | VAF 11/53 reads (21%) | catalogued as rs747248693; called by mutect2, varscan2
- CSPP1 | c.3445A>G p.S1149G (on ENST00000676605; = p.S1108G on NM_024790.6) | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT tolerated (0.25); PolyPhen benign (0.045); catalogued as COSV51587517; called by muse, mutect2, varscan2
- CSRNP2 | c.545G>A p.R182Q | Missense Mutation (SNP) | VAF 29/147 reads (20%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.995); catalogued as rs148149139; called by muse, mutect2, varscan2
- CSRNP3 | c.1657A>G p.I553V | Missense Mutation (SNP) | VAF 28/123 reads (23%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV58781221; called by muse, mutect2, varscan2
- CTNNAL1 | c.2087T>C p.M696T | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.01); catalogued as rs1465135033, COSV57703975; called by muse, mutect2, varscan2
- CTNND1 | c.1285T>C p.C429R | Missense Mutation (SNP) | VAF 35/196 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62384638; called by muse, varscan2
- CTTNBP2 | c.2119dup p.L707Pfs*25 | Frame Shift Ins (INS) | VAF 19/144 reads (13%) | catalogued as rs1394935268; called by mutect2, pindel, varscan2
- CUL1 | c.439C>T p.R147C | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV57390008; called by muse, mutect2, varscan2
- CUL7 | c.499A>G p.M167V | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.965); catalogued as COSV54819188; called by muse, mutect2, varscan2
- CUX1 | c.1289dup p.P431Sfs*16 | Frame Shift Ins (INS) | VAF 12/105 reads (11%) | catalogued as rs782381199; called by mutect2, varscan2
- CXXC1 | c.1276G>A p.G426S | Missense Mutation (SNP) | VAF 25/124 reads (20%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.738); catalogued as rs1166244777, COSV53273010; called by muse, mutect2, varscan2
- CYLC1 | c.656A>C p.N219T | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.199); catalogued as COSV61413540; called by muse, mutect2, varscan2
- CYP46A1 | c.1198C>T p.R400W | Missense Mutation (SNP) | VAF 11/88 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55894769; called by muse, mutect2, varscan2
- DAXX | c.788G>A p.R263H | Missense Mutation (SNP) | VAF 27/126 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1429735040, COSV56469008; called by muse, mutect2, varscan2
- DCAF4 | c.1033T>C p.S345P | Missense Mutation (SNP) | VAF 25/206 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.493); catalogued as COSV62319969; called by muse, mutect2, varscan2
- DCC | c.1994C>T p.T665M | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.894); catalogued as rs369809232; called by muse, mutect2, varscan2
- DCST1 | c.1544G>A p.R515Q | Missense Mutation (SNP) | VAF 22/105 reads (21%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.83); catalogued as rs138386761; called by muse, mutect2, varscan2
- DDI1 | c.503C>T p.A168V | Missense Mutation (SNP) | VAF 17/141 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs765717385, COSV56369127; called by muse, mutect2, varscan2
- DDX31 | c.2080C>T p.Q694* | Nonsense Mutation (SNP) | VAF 17/122 reads (14%) | catalogued as COSV64650198; called by muse, mutect2, varscan2
- DDX60L | c.2933T>G p.V978G | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.478); catalogued as COSV52716614; called by muse, mutect2, varscan2
- DENND2A | c.475G>A p.V159M | Missense Mutation (SNP) | VAF 26/138 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as rs573861843, COSV52054083; called by muse, mutect2, varscan2
- DIAPH3 | c.958del p.I320Lfs*20 (on ENST00000400324 / NM_001042517.2; = p.I57Lfs*20 on NM_030932.3) | Frame Shift Del (DEL) | VAF 24/82 reads (29%) | catalogued as rs755069320; called by mutect2, varscan2
- DKC1 | c.498del p.T167Pfs*7 | Frame Shift Del (DEL) | VAF 19/102 reads (19%) | catalogued as COSV65777295; called by mutect2, pindel, varscan2
- DLL1 | c.1156G>A p.D386N | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT tolerated (0.78); PolyPhen benign (0.16); catalogued as rs372640222; called by muse, mutect2, varscan2
- DLL1 | c.376G>A p.A126T | Missense Mutation (SNP) | VAF 13/99 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV64537939; called by muse, mutect2, varscan2
- DMC1 | c.815C>T p.A272V | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.423); catalogued as rs868443703, COSV53259762; called by muse, mutect2, varscan2
- DNAH10 | c.11683C>T p.R3895C (on ENST00000409039; = p.R3834C on NM_207437.3) | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs767910055, COSV68996465; called by muse, varscan2
- DNAH3 | c.8687G>A p.R2896H | Missense Mutation (SNP) | VAF 36/204 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs748512714, COSV54519440; called by muse, mutect2, varscan2
- DNAH5 | c.11846T>G p.L3949R | Missense Mutation (SNP) | VAF 19/101 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1334354600, COSV54201621, COSV54257873; called by muse, mutect2, varscan2
- DNAH9 | c.6521G>A p.R2174H | Missense Mutation (SNP) | VAF 24/111 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as rs752731038, COSV52358855; called by muse, mutect2, varscan2
- DNAJC6 | c.860C>A p.P287H | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV54777694; called by muse, mutect2, varscan2
- DNHD1 | c.12660A>G p.P4220= | Splice Region (SNP) | VAF 7/56 reads (13%) | catalogued as COSV99601178; called by muse, mutect2, varscan2
- DOCK3 | c.431G>A p.R144Q | Missense Mutation (SNP) | VAF 24/107 reads (22%) | SIFT tolerated (0.39); PolyPhen benign (0.153); catalogued as rs1441269593, COSV56532239; called by muse, mutect2, varscan2
- DOK5 | c.383C>T p.A128V | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.935); catalogued as COSV52822337, COSV52827984; called by muse, mutect2, varscan2
- DPEP2 | c.1402del p.H468Tfs*51 | Frame Shift Del (DEL) | VAF 21/146 reads (14%) | catalogued as rs1023404475, COSV52055402; called by mutect2, varscan2
- DSC2 | c.1814G>A p.G605D | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); catalogued as rs1342808624, COSV51863584; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DUS4L-BCAP29 | c.1060del p.W354Gfs*2 | Frame Shift Del (DEL) | VAF 9/43 reads (21%) | catalogued as rs746928635; called by mutect2, pindel, varscan2
- DUSP1 | c.973G>A p.A325T | Missense Mutation (SNP) | VAF 16/106 reads (15%) | SIFT tolerated (0.33); PolyPhen benign (0.025); catalogued as rs202068138, COSV53320487; called by muse, mutect2, varscan2
- DUSP5 | c.59C>T p.A20V | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0.076); catalogued as rs372205197; called by muse, mutect2, varscan2
- DYSF | c.2746G>T p.D916Y | Missense Mutation (SNP) | VAF 76/549 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV50464650; called by muse, mutect2, varscan2
- DYSF | c.6065A>G p.D2022G | Missense Mutation (SNP) | VAF 18/180 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.665); catalogued as COSV50464824; called by muse, mutect2
- EFCAB6 | c.4489C>T p.R1497W | Missense Mutation (SNP) | VAF 20/87 reads (23%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as rs200755477; called by muse, mutect2, varscan2
- EHMT1 | c.1742G>A p.R581H | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.043); catalogued as COSV58377587; called by muse, mutect2, varscan2
- EIF4G1 | c.302G>T p.G101V | Missense Mutation (SNP) | VAF 14/95 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); catalogued as COSV59992123; called by muse, mutect2, varscan2
- EIF4G1 | c.1763A>G p.Q588R (on ENST00000346169 / NM_198241.3; = p.Q392R on NM_004953.5) | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.04); catalogued as rs747836331, COSV59992130; called by muse, mutect2, varscan2
- ELMO1 | c.1826C>T p.P609L | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.281); catalogued as rs751395548, COSV60305620; called by muse, mutect2, varscan2
- ELMO1 | c.1241G>A p.G414D | Missense Mutation (SNP) | VAF 6/69 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV60295080; called by muse, mutect2
- EML1 | c.1372G>A p.A458T | Missense Mutation (SNP) | VAF 17/102 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.921); catalogued as COSV51748111; called by muse, mutect2, varscan2
- ENDOV | c.248G>A p.R83H | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as rs759977970, COSV100108622; called by muse, varscan2
- EPB41 | c.1552A>G p.R518G (on ENST00000343067 / NM_001166005.2; = p.R309G on NM_004437.4) | Missense Mutation (SNP) | VAF 16/122 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV58049902; called by muse, mutect2, varscan2
- EPS8L2 | c.1412dup p.D473Gfs*30 | Frame Shift Ins (INS) | VAF 12/83 reads (14%) | catalogued as rs780857388; called by mutect2, varscan2
- ERF | c.896del p.G299Efs*12 | Frame Shift Del (DEL) | VAF 7/37 reads (19%) | catalogued as rs780487406; called by mutect2, pindel
- ERGIC3 | c.806C>T p.A269V | Missense Mutation (SNP) | VAF 30/210 reads (14%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.638); catalogued as rs1005404363, COSV53414807; called by muse, mutect2, varscan2
- ERN1 | c.1825G>A p.A609T | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs1365942225, COSV70500307, COSV70503105; called by mutect2, varscan2
- ESR2 | c.137T>C p.M46T | Missense Mutation (SNP) | VAF 16/112 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.014); catalogued as COSV50833965; called by muse, mutect2, varscan2
- ESRP1 | c.1535del p.N512Tfs*2 | Frame Shift Del (DEL) | VAF 10/78 reads (13%) | catalogued as rs775950025; called by mutect2, varscan2
- ESRP1 | c.1708G>A p.A570T | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.316); catalogued as COSV64410882; called by muse, mutect2, varscan2
- ESS2 | c.173A>C p.D58A | Missense Mutation (SNP) | VAF 24/179 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV52817543; called by muse, mutect2, varscan2
- ETV4 | c.1012C>T p.R338W | Missense Mutation (SNP) | VAF 24/156 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs746787291, COSV52254507; called by muse, mutect2, varscan2
- EXOC1 | c.635A>G p.K212R | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.115); catalogued as COSV62120968; called by muse, varscan2
- EXOC3L1 | c.1742C>T p.T581M | Missense Mutation (SNP) | VAF 29/126 reads (23%) | SIFT tolerated (0.23); PolyPhen benign (0.015); catalogued as rs201658978, COSV52047217; called by muse, mutect2, varscan2
- F13B | c.529C>A p.Q177K | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT tolerated (0.54); PolyPhen benign (0.046); catalogued as COSV66374579; called by muse, mutect2, varscan2
- F8 | c.6521A>G p.H2174R | Missense Mutation (SNP) | VAF 22/94 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.216); catalogued as CM129829, COSV57705730; called by muse, mutect2, varscan2
- FAHD2B | c.842del p.P281Qfs*26 | Frame Shift Del (DEL) | VAF 5/38 reads (13%) | catalogued as rs751966944; called by mutect2, varscan2
- FAM162B | c.275G>A p.R92Q | Missense Mutation (SNP) | VAF 21/101 reads (21%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as COSV63920468; called by muse, mutect2, varscan2
- FAM209A | c.307del p.R103Efs*14 | Frame Shift Del (DEL) | VAF 19/125 reads (15%) | catalogued as COSV54769575; called by mutect2, pindel, varscan2
- FAM50B | c.256C>T p.R86W | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as COSV66654928; called by muse, mutect2
- FAM71F1 | c.642C>G p.H214Q | Missense Mutation (SNP) | VAF 19/135 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV59374110; called by muse, mutect2, varscan2
- FAM71F1 | c.1001C>A p.P334Q | Missense Mutation (SNP) | VAF 20/181 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.916); catalogued as COSV59374119; called by muse, mutect2, varscan2
- FANCE | c.929dup p.V311Sfs*2 | Frame Shift Ins (INS) | VAF 16/74 reads (22%) | catalogued as rs587778337; ClinVar: not provided; called by mutect2, varscan2
- FANCG | c.19T>G p.S7A | Missense Mutation (SNP) | VAF 26/127 reads (20%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV66213726, COSV66213869; called by muse, mutect2, varscan2
- FAP | c.609G>T p.E203D | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.897); catalogued as COSV51864103; called by muse, mutect2, varscan2
- FASN | c.2915C>T p.P972L | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT tolerated (0.39); PolyPhen benign (0.037); catalogued as rs202024339, COSV60757320; called by muse, mutect2, varscan2
- FBN1 | c.8405G>A p.G2802D | Missense Mutation (SNP) | VAF 19/91 reads (21%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.569); catalogued as rs770484928, COSV57322221; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FBN3 | c.5378G>A p.R1793Q | Missense Mutation (SNP) | VAF 18/112 reads (16%) | SIFT tolerated (0.49); PolyPhen benign (0.009); catalogued as rs143230386, COSV54465166, COSV99561951; called by muse, mutect2, varscan2
- FBN3 | c.4036C>T p.R1346C | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.807); catalogued as rs749453532, COSV54455724; called by muse, mutect2, varscan2
- FBXO38 | c.130T>C p.Y44H | Missense Mutation (SNP) | VAF 7/80 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.593); catalogued as COSV57029173; called by muse, mutect2
- FIBP | c.199G>A p.E67K | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1434231911, COSV100327591; called by muse, mutect2, varscan2
- FLNB | c.6866G>A p.R2289H | Missense Mutation (SNP) | VAF 5/78 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.977); catalogued as rs1033252725, COSV55896876; called by muse, mutect2
- FMNL3 | c.998C>T p.S333L | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV53304202; called by muse, mutect2, varscan2
- FNIP2 | c.1232del p.N411Tfs*14 | Frame Shift Del (DEL) | VAF 8/50 reads (16%) | catalogued as rs775387591; called by mutect2, pindel, varscan2
- FRAS1 | c.6725A>C p.Q2242P | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV53624585; called by muse, mutect2, varscan2
- FRMD5 | c.1037T>C p.M346T | Missense Mutation (SNP) | VAF 12/108 reads (11%) | SIFT tolerated (0.45); PolyPhen benign (0.006); catalogued as COSV68723407; called by muse, mutect2, varscan2
- GALNT17 | c.506T>C p.L169P | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as COSV61171053; called by muse, mutect2, varscan2
- GALR2 | c.622G>A p.A208T | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0.028); catalogued as rs142971884; called by muse, mutect2, varscan2
- GART | c.2316T>C p.G772= | Splice Region (SNP) | VAF 12/37 reads (32%) | catalogued as COSV67819034; called by muse, mutect2, varscan2
- GART | c.722A>G p.Q241R | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.909); catalogued as COSV63113831; called by muse, mutect2, varscan2
- GASK1B | c.757G>A p.A253T | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as rs762471143, COSV56704800; called by muse, mutect2, varscan2
- GATB | c.794C>T p.S265F | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56131533; called by muse, mutect2, varscan2
- GATD1 | c.142-1G>T p.X48_splice | Splice Site (SNP) | VAF 10/60 reads (17%) | catalogued as COSV60592824, COSV60593601; called by muse, mutect2
- GBP6 | c.701T>C p.F234S | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65011937; called by muse, varscan2
- GDPD4 | c.1474C>T p.R492W | Missense Mutation (SNP) | VAF 25/115 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs549224703, COSV60016851; called by muse, mutect2, varscan2
- GFM2 | c.1159C>T p.R387C | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs866401948, COSV57191751; called by muse, mutect2, varscan2
- GFRA3 | c.378T>C p.L126= | Splice Region (SNP) | VAF 10/85 reads (12%) | catalogued as COSV51229342; called by muse, varscan2
- GFRA3 | c.338G>A p.C113Y | Missense Mutation (SNP) | VAF 10/87 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51229357; called by muse, varscan2
- GGN | c.344C>T p.A115V | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.011); catalogued as rs747657588, COSV53057607; called by muse, mutect2
- GLG1 | c.1256G>A p.C419Y | Missense Mutation (SNP) | VAF 22/136 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52669884; called by muse, mutect2, varscan2
- GLI3 | c.3116C>T p.A1039V | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV67890781, COSV99060470; called by muse, mutect2, varscan2
- GLRA1 | c.449G>A p.R150Q | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT tolerated (0.24); PolyPhen benign (0.426); catalogued as rs561848502, COSV51007409; ClinVar: conflicting interpretations of pathogenicity; called by muse, varscan2
- GMEB2 | c.1436C>T p.T479M | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as COSV56607920; called by muse, mutect2
- GNAZ | c.256C>T p.R86W | Missense Mutation (SNP) | VAF 46/298 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.492); catalogued as rs1366225244, COSV50739552; called by muse, mutect2, varscan2
- GNL2 | c.1793A>C p.K598T | Missense Mutation (SNP) | VAF 36/226 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.193); catalogued as COSV56170516; called by muse, mutect2, varscan2
- GOLGB1 | c.4222G>A p.V1408I | Missense Mutation (SNP) | VAF 22/123 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs764751569, COSV61467607; called by muse, mutect2, varscan2
- GOPC | c.811G>T p.G271C | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.72); catalogued as COSV50002762; called by muse, mutect2, varscan2
- GPBP1 | c.829_831del p.P277del | In Frame Del (DEL) | VAF 13/52 reads (25%) | catalogued as rs992774076; called by mutect2, pindel, varscan2
- GREM2 | c.154G>A p.V52M | Missense Mutation (SNP) | VAF 10/81 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.528); catalogued as COSV100548093; called by muse, varscan2
- GRIA2 | c.632G>A p.C211Y | Missense Mutation (SNP) | VAF 21/112 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV52396307; called by muse, mutect2, varscan2
- GRID2 | c.689C>T p.A230V | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.989); catalogued as rs1282591728, COSV56226121; called by muse, mutect2
- GRM7 | c.2594C>T p.A865V | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as rs55716077; called by muse, mutect2, varscan2
- GRM8 | c.966G>T p.E322D | Missense Mutation (SNP) | VAF 26/136 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.516); catalogued as COSV100286879; called by muse, mutect2, varscan2
- GSDMC | c.844G>A p.E282K | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as COSV99416689; called by mutect2, varscan2
- GSTM4 | c.286C>T p.R96C | Missense Mutation (SNP) | VAF 15/101 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.181); catalogued as rs761147429, COSV58695205; called by muse, mutect2, varscan2
- GTF2H4 | c.280C>T p.R94W | Missense Mutation (SNP) | VAF 31/167 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); catalogued as rs767371516, COSV52559090; called by muse, mutect2, varscan2
- GTF2I | c.809C>T p.S270L | Missense Mutation (SNP) | VAF 15/108 reads (14%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as rs781866719, COSV60399825; called by muse, mutect2, varscan2
- GTF3C1 | c.2299del p.S767Vfs*7 | Frame Shift Del (DEL) | VAF 15/69 reads (22%) | catalogued as rs1231771183; called by mutect2, pindel, varscan2
- GTF3C3 | c.1081del p.T361Lfs*26 | Frame Shift Del (DEL) | VAF 8/36 reads (22%) | catalogued as rs750792116; called by mutect2, varscan2
- GUCY2D | c.1883A>G p.Q628R | Missense Mutation (SNP) | VAF 11/94 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.027); catalogued as COSV54697145; called by muse, mutect2, varscan2
- HCK | c.820G>A p.G274R | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV52944587; called by muse, mutect2, varscan2
- HCN4 | c.1471G>A p.D491N | Missense Mutation (SNP) | VAF 18/112 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1060500107, COSV56085042; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HDGFL2 | c.677del p.K226Rfs*45 | Frame Shift Del (DEL) | VAF 20/98 reads (20%) | catalogued as rs1219916331, COSV56682191; called by mutect2, varscan2
- HDLBP | c.2092G>A p.D698N | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.451); catalogued as rs1019420712, COSV100191807, COSV60496726; called by muse, mutect2, varscan2
- HEBP2 | c.397G>T p.A133S | Missense Mutation (SNP) | VAF 28/171 reads (16%) | SIFT tolerated (0.33); PolyPhen benign (0.061); catalogued as COSV62928359; called by muse, mutect2, varscan2
- HECTD1 | c.5101T>C p.Y1701H | Missense Mutation (SNP) | VAF 14/140 reads (10%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.543); catalogued as COSV67947485; called by muse, mutect2, varscan2
- HECTD1 | c.1987T>C p.W663R | Missense Mutation (SNP) | VAF 33/175 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV67947488; called by muse, mutect2, varscan2
- HEPH | c.2210T>C p.I737T (on ENST00000343002; = p.I470T on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/59 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.213); catalogued as COSV57959740, COSV57966809; called by muse, mutect2
- HGFAC | c.1898G>A p.R633H | Missense Mutation (SNP) | VAF 20/98 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.786); catalogued as rs374846787; called by muse, mutect2, varscan2
- HIP1 | c.703C>T p.L235F | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV61188182; called by muse, mutect2, varscan2
- HLTF | c.172G>A p.V58I | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as rs1438830457, COSV59501948; called by muse, mutect2, varscan2
- HNRNPF | c.1157A>C p.Q386P | Missense Mutation (SNP) | VAF 30/185 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.397); catalogued as COSV61561570; called by muse, mutect2, varscan2
- HNRNPH1 | c.673G>T p.G225* | Nonsense Mutation (SNP) | VAF 23/167 reads (14%) | catalogued as COSV61485067, COSV61485721, COSV61487087; called by muse, mutect2, varscan2
- HOXB1 | c.239C>T p.A80V | Missense Mutation (SNP) | VAF 24/124 reads (19%) | SIFT tolerated (0.33); PolyPhen benign (0.068); catalogued as rs765050616, COSV53317864; called by muse, mutect2, varscan2
- HOXD11 | c.209G>A p.R70H | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.28); PolyPhen benign (0.006); catalogued as rs752077506, COSV50912034; called by muse, mutect2
- HRNR | c.1003C>T p.R335C | Missense Mutation (SNP) | VAF 37/171 reads (22%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as rs201065916, COSV100914064, COSV64258916; called by muse, mutect2, varscan2
- HS3ST2 | c.746G>A p.R249H | Missense Mutation (SNP) | VAF 24/191 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.381); catalogued as COSV54460373, COSV54463153; called by muse, varscan2
- HSF4 | c.506G>A p.R169Q | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs1328322791, COSV50458041; called by muse, mutect2, varscan2
- HTR3B | c.707G>A p.R236H | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); catalogued as rs766819022, COSV52743050; called by muse, mutect2, varscan2
- HTR3E | c.329T>C p.I110T (on ENST00000415389 / NM_001256613.1; = p.I125T on NM_182589.2) | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.398); catalogued as COSV58947577; called by muse, mutect2, varscan2
- IARS1 | c.719C>T p.P240L | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV65116021; called by muse, mutect2, varscan2
- ICA1 | c.611del p.N204Tfs*5 | Frame Shift Del (DEL) | VAF 7/38 reads (18%) | catalogued as rs747841314; called by mutect2, varscan2
- ICE2 | c.1899del p.K633Nfs*17 | Frame Shift Del (DEL) | VAF 6/44 reads (14%) | catalogued as COSV55031693; called by mutect2, pindel
- IFIT5 | c.1148G>A p.G383D | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV65655269; called by mutect2, varscan2
- IGHA1 | c.701C>T p.P234L | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs759216050; called by muse, mutect2, varscan2
- IGHA2 | c.662C>T p.P221L | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs782085693; called by mutect2, varscan2
- IGHV1-69 | c.170G>A p.R57Q | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.124); catalogued as rs552203860; called by mutect2, varscan2
- IKZF1 | c.1273G>A p.G425R | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs1459868445, COSV58792366; called by muse, mutect2
- IL1RAPL2 | c.929A>C p.K310T | Missense Mutation (SNP) | VAF 17/102 reads (17%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.946); catalogued as COSV61166234; called by muse, mutect2, varscan2
- IL20RA | c.646G>A p.V216I | Missense Mutation (SNP) | VAF 29/136 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0.147); catalogued as rs752578754, COSV57359083; called by muse, mutect2, varscan2
- IMPG2 | c.239G>A p.R80Q | Missense Mutation (SNP) | VAF 17/115 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.011); catalogued as rs751226839, COSV51972922; called by muse, mutect2, varscan2
- INO80B | c.504G>T p.K168N | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV51970412; called by muse, mutect2, varscan2
- INSM2 | c.964G>A p.A322T | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as COSV51888398; called by muse, mutect2, varscan2
- IPO4 | c.451G>A p.E151K | Missense Mutation (SNP) | VAF 24/145 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.251); catalogued as rs749422296, COSV55780721; called by muse, mutect2, varscan2
- IRAK2 | c.1336G>A p.V446M | Missense Mutation (SNP) | VAF 10/134 reads (7%) | SIFT tolerated (0.2); PolyPhen benign (0.134); catalogued as COSV56530950; called by muse, mutect2
- IRGQ | c.373G>A p.A125T | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.007); catalogued as rs529378941, COSV60670980; called by muse, mutect2, varscan2
- IRS1 | c.1791del p.H598Tfs*38 | Frame Shift Del (DEL) | VAF 7/46 reads (15%) | catalogued as rs761880048; called by mutect2, varscan2
- IRS4 | c.3416C>T p.A1139V | Missense Mutation (SNP) | VAF 48/216 reads (22%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.003); catalogued as COSV64534626; called by muse, mutect2, varscan2
- ITGA7 | c.428G>A p.R143Q | Missense Mutation (SNP) | VAF 25/110 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.485); catalogued as rs537937026, COSV57697273, COSV99151724; called by muse, mutect2, varscan2
- ITGAL | c.2602T>G p.F868V | Missense Mutation (SNP) | VAF 11/90 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.696); catalogued as COSV63323076; called by muse, mutect2, varscan2
- ITGB1 | c.719G>A p.R240H | Missense Mutation (SNP) | VAF 13/93 reads (14%) | SIFT tolerated (0.58); PolyPhen benign (0.003); catalogued as rs371485643; called by muse, mutect2, varscan2
- ITGB8 | c.2224G>A p.V742I | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.293); catalogued as COSV56010757; called by muse, mutect2, varscan2
- ITPK1 | c.811C>T p.Q271* | Nonsense Mutation (SNP) | VAF 13/128 reads (10%) | catalogued as COSV50896925; called by muse, mutect2, varscan2
- ITPR1 | c.479G>T p.W160L | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV56989906; called by muse, mutect2, varscan2
- ITPR3 | c.5164G>A p.A1722T | Missense Mutation (SNP) | VAF 28/142 reads (20%) | SIFT tolerated (0.3); PolyPhen benign (0.031); catalogued as rs756479384, COSV65408940; called by muse, mutect2, varscan2
- ITPR3 | c.7570C>T p.R2524C | Missense Mutation (SNP) | VAF 7/74 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65267690; called by muse, mutect2
- KAAG1 | c.197C>T p.A66V | Missense Mutation (SNP) | VAF 23/96 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); catalogued as rs753161246, COSV51239803; called by muse, mutect2, varscan2
- KANK2 | c.848C>T p.A283V | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.438); catalogued as COSV62008873; called by muse, mutect2, varscan2
- KANSL1 | c.1337T>C p.V446A | Missense Mutation (SNP) | VAF 27/169 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.577); catalogued as COSV52270614; called by muse, mutect2, varscan2
- KCNA4 | c.663del p.F221Lfs*21 | Frame Shift Del (DEL) | VAF 11/83 reads (13%) | catalogued as rs754892524; called by mutect2, pindel, varscan2
- KCNB1 | c.877C>T p.R293C | Missense Mutation (SNP) | VAF 18/97 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65565964, COSV65567065; called by muse, mutect2, varscan2
- KCNC1 | c.1370del p.K457Rfs*20 | Frame Shift Del (DEL) | VAF 16/92 reads (17%) | catalogued as COSV99789491; called by mutect2, varscan2
- KCNJ14 | c.1039C>T p.R347C | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs750940601, COSV60738346, COSV60738731; called by muse, mutect2, varscan2
- KCNK18 | c.568C>A p.P190T | Missense Mutation (SNP) | VAF 16/115 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs372982639, COSV100572163; called by muse, mutect2, varscan2
- KDM6B | c.4696C>A p.R1566S | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.714); catalogued as COSV54683592; called by muse, mutect2, varscan2
- KIAA0100 | c.4111C>T p.R1371W | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1387008111, COSV66494486; called by muse, mutect2, varscan2
- KIAA1109 | c.8849C>A p.T2950N | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.367); catalogued as COSV52681109; called by muse, mutect2, varscan2
- KIAA1109 | c.10615C>T p.R3539C | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs765987499, COSV52681131; called by muse, mutect2, varscan2
- KIAA1549 | c.697C>T p.R233W | Missense Mutation (SNP) | VAF 28/157 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs369822469; called by muse, mutect2, varscan2
- KIAA1958 | c.1373T>A p.L458H | Missense Mutation (SNP) | VAF 19/129 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV61725240; called by muse, mutect2, varscan2
- KIDINS220 | c.1960del p.T654Hfs*34 | Frame Shift Del (DEL) | VAF 6/52 reads (12%) | catalogued as COSV56750986; called by mutect2, pindel, varscan2
- KIF16B | c.2657C>T p.T886M | Missense Mutation (SNP) | VAF 16/100 reads (16%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.084); catalogued as rs972012083, COSV61708837; called by muse, mutect2, varscan2
- KIF1A | c.1624G>A p.V542I | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs373891682; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KIF21B | c.2887C>T p.R963W | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.226); catalogued as rs764862669, COSV59760909; called by muse, mutect2, varscan2
- KIF26B | c.5837G>T p.R1946L | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.78); catalogued as COSV63645163; called by muse, mutect2, varscan2
- KIF5B | c.733G>T p.G245C | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56654047; called by muse, mutect2, varscan2
- KLB | c.14G>A p.C5Y | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); catalogued as rs775315888, COSV57302819; called by muse, mutect2, varscan2
- KMT2C | c.1256A>G p.Q419R | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.525); catalogued as COSV51278136; called by muse, mutect2, varscan2
- KPNB1 | c.1637C>T p.A546V | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV51598352; called by muse, mutect2
- KRT23 | c.307C>T p.R103C | Missense Mutation (SNP) | VAF 22/138 reads (16%) | SIFT tolerated (0.32); PolyPhen benign (0.007); catalogued as COSV52928342; called by muse, mutect2, varscan2
- LAD1 | c.443G>A p.R148Q | Missense Mutation (SNP) | VAF 20/129 reads (16%) | SIFT tolerated (0.64); PolyPhen benign (0.014); catalogued as rs112179009; called by muse, mutect2, varscan2
- LAMA4 | c.1540C>T p.R514W (on ENST00000230538 / NM_001105206.3; = p.R507W on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); catalogued as rs782767592, COSV57896200; called by muse, mutect2, varscan2
- LAMB2 | c.784C>A p.P262T | Missense Mutation (SNP) | VAF 14/96 reads (15%) | SIFT tolerated (0.28); PolyPhen benign (0.171); catalogued as COSV59735202; called by muse, mutect2, varscan2
- LAMB4 | c.3076G>A p.A1026T | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT tolerated (0.62); PolyPhen benign (0.113); catalogued as COSV52723391; called by muse, mutect2, varscan2
- LAMB4 | c.2726G>A p.R909H | Missense Mutation (SNP) | VAF 17/102 reads (17%) | SIFT tolerated (0.27); PolyPhen benign (0.007); catalogued as rs146445677, COSV52729295; called by muse, mutect2, varscan2
- LAMC3 | c.1130G>A p.R377Q | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs375139277; called by muse, mutect2, varscan2
- LARP4 | c.*4del | Frame Shift Del (DEL) | VAF 4/45 reads (9%) | catalogued as rs1195324784; called by mutect2, pindel
- LCOR | c.3854G>A p.S1285N | Missense Mutation (SNP) | VAF 20/113 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0.012); catalogued as rs199889747, COSV53716947; called by muse, mutect2, varscan2
- LILRB5 | c.536T>C p.L179P | Missense Mutation (SNP) | VAF 12/98 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV60259249; called by muse, mutect2, varscan2
- LMLN | c.1622T>C p.L541P | Missense Mutation (SNP) | VAF 24/116 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.027); catalogued as COSV57602534; called by muse, mutect2, varscan2
- LMO3 | c.53G>A p.R18Q | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT tolerated (0.4); PolyPhen benign (0.013); catalogued as rs754453605, COSV53783638, COSV99662815; called by muse, mutect2, varscan2
- LMTK2 | c.2461G>A p.E821K | Missense Mutation (SNP) | VAF 34/152 reads (22%) | SIFT tolerated (0.69); PolyPhen benign (0.001); catalogued as rs944335712, COSV51998976; called by muse, mutect2, varscan2
- LOXL3 | c.1753C>A p.H585N | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.687); catalogued as COSV99240032; called by muse, mutect2, varscan2
- LOXL3 | c.824del p.G275Afs*5 | Frame Shift Del (DEL) | VAF 24/108 reads (22%) | catalogued as rs746133895; called by mutect2, varscan2
- LPAR3 | c.139del p.S47Lfs*9 | Frame Shift Del (DEL) | VAF 20/112 reads (18%) | catalogued as rs762083435; called by mutect2, varscan2
- LPAR4 | c.433C>T p.R145* | Nonsense Mutation (SNP) | VAF 22/111 reads (20%) | catalogued as rs1407911813, COSV70912324; called by muse, mutect2, varscan2
- LPO | c.245G>A p.R82H | Missense Mutation (SNP) | VAF 11/106 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs765461792, COSV51858206; called by muse, mutect2, varscan2
- LRAT | c.259C>T p.R87C | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.72); catalogued as COSV60476672; called by muse, mutect2, varscan2
- LRP12 | c.78C>T p.Y26= | Splice Region (SNP) | VAF 6/40 reads (15%) | catalogued as COSV52630678; called by muse, mutect2
- LRRC41 | c.2359C>T p.R787W | Missense Mutation (SNP) | VAF 18/93 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1191625633, COSV58440807; called by muse, mutect2, varscan2
- LRRN3 | c.1167G>A p.M389I | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT tolerated (0.58); PolyPhen benign (0.292); catalogued as COSV100071987, COSV57821504; called by muse, mutect2, varscan2
- LTBP1 | c.3766A>C p.S1256R (on ENST00000404816 / NM_206943.4; = p.S930R on NM_000627.4) | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT tolerated (0.26); PolyPhen benign (0.006); catalogued as COSV55381554; called by muse, mutect2, varscan2
- MACO1 | c.306del p.F102Lfs*47 | Frame Shift Del (DEL) | VAF 5/31 reads (16%) | catalogued as rs752439249; called by mutect2, varscan2
- MAN2A2 | c.1252G>A p.V418I | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as rs145039941; called by muse, varscan2
- MAP10 | c.1450C>T p.R484C | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as COSV69364043; called by muse, mutect2, varscan2
- MAP7D1 | c.245dup p.Q83Afs*8 | Frame Shift Ins (INS) | VAF 13/83 reads (16%) | catalogued as rs765962881; called by mutect2, varscan2
- MAPK7 | c.2357G>A p.G786D | Missense Mutation (SNP) | VAF 19/103 reads (18%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.656); catalogued as COSV55191044; called by muse, mutect2, varscan2
- MBD6 | c.2345dup p.A783Sfs*10 | Frame Shift Ins (INS) | VAF 17/82 reads (21%) | catalogued as rs746267361; called by mutect2, varscan2
- MBNL3 | c.707C>T p.A236V | Missense Mutation (SNP) | VAF 18/114 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.341); catalogued as COSV63731156; called by muse, mutect2, varscan2
- MBNL3 | c.191G>A p.R64Q | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63731725; called by muse, mutect2, varscan2
- MCC | c.1592C>T p.A531V | Missense Mutation (SNP) | VAF 21/147 reads (14%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.011); catalogued as COSV56731488; called by muse, mutect2, varscan2
- MCF2L | c.2876C>T p.A959V (on ENST00000375608; = p.A927V on NM_024979.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs565147618, COSV56179261; called by muse, mutect2, varscan2
- MCM2 | c.1652C>T p.A551V | Missense Mutation (SNP) | VAF 26/172 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs781253937, COSV54034918; called by muse, mutect2, varscan2
- MDC1 | c.5008G>A p.V1670I | Missense Mutation (SNP) | VAF 24/155 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.204); catalogued as rs200530869, COSV64525312; called by muse, mutect2, varscan2
- MDN1 | c.6440G>A p.W2147* | Nonsense Mutation (SNP) | VAF 15/92 reads (16%) | catalogued as COSV65524478; called by muse, mutect2, varscan2
- MDN1 | c.6170A>C p.Q2057P | Missense Mutation (SNP) | VAF 17/99 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.424); catalogued as COSV65524486; called by muse, mutect2, varscan2
- MDN1 | c.4214C>T p.A1405V | Missense Mutation (SNP) | VAF 14/102 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.156); catalogued as COSV65524493; called by muse, mutect2, varscan2
- MEGF11 | c.844C>T p.Q282* | Nonsense Mutation (SNP) | VAF 10/47 reads (21%) | catalogued as COSV56554159; called by muse, mutect2, varscan2
- MEGF8 | c.497del p.G166Vfs*53 | Frame Shift Del (DEL) | VAF 9/54 reads (17%) | catalogued as rs762115034; called by mutect2, pindel
- MEOX1 | c.739T>C p.S247P | Missense Mutation (SNP) | VAF 16/158 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs78282512, COSV59355844, COSV59356604; called by muse, mutect2
- MEX3A | c.1045T>G p.S349A | Missense Mutation (SNP) | VAF 15/119 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.058); catalogued as rs747913417, COSV68479197; called by muse, mutect2, varscan2
- MEX3B | c.910G>A p.G304R | Missense Mutation (SNP) | VAF 17/119 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV61663677; called by muse, mutect2, varscan2
- MFSD14A | c.806del p.L269Yfs*6 | Frame Shift Del (DEL) | VAF 12/70 reads (17%) | catalogued as rs780635289; called by mutect2, varscan2
- MIER1 | c.145A>G p.T49A (on ENST00000355356 / NM_001077701.3; = p.T66A on NM_020948.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT tolerated (0.36); PolyPhen benign (0.007); catalogued as COSV62530906; called by muse, mutect2
- MKI67 | c.698del p.N233Mfs*12 | Frame Shift Del (DEL) | VAF 9/42 reads (21%) | catalogued as rs749903408; called by mutect2, varscan2
- MN1 | c.3089G>A p.G1030D | Missense Mutation (SNP) | VAF 20/142 reads (14%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.177); catalogued as COSV56559753; called by muse, mutect2, varscan2
- MORC4 | c.1del p.M1? | Frame Shift Del (DEL) | VAF 14/87 reads (16%) | catalogued as rs759643903; called by mutect2, pindel, varscan2
- MROH2B | c.4114del p.I1372Sfs*5 | Frame Shift Del (DEL) | VAF 13/85 reads (15%) | catalogued as rs756600463; called by mutect2, varscan2
- MRPS23 | c.439G>A p.V147I | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs761410726, COSV58032469; called by muse, mutect2, varscan2
- MRTFB | c.3229A>G p.S1077G (on ENST00000571589 / NM_001365412.2; = p.S1027G on NM_014048.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/85 reads (13%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV57959166; called by muse, mutect2, varscan2
- MSLN | c.767G>C p.G256A | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.433); catalogued as COSV53503711; called by muse, mutect2, varscan2
- MTHFSD | c.247del p.T83Hfs*9 (on ENST00000360900 / NM_001159377.2; = p.T82Hfs*9 on NM_022764.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 8/49 reads (16%) | catalogued as rs1266793672; called by mutect2, varscan2
- MTMR4 | c.21del p.S8Afs*16 | Frame Shift Del (DEL) | VAF 11/104 reads (11%) | catalogued as COSV60203880; called by mutect2, pindel, varscan2
- MTOR | c.931C>T p.R311C | Missense Mutation (SNP) | VAF 27/143 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs200901835; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MUC4 | c.15265G>A p.V5089I (on ENST00000463781 / NM_018406.7; = p.V853I on NM_004532.6) | Missense Mutation (SNP) | VAF 13/122 reads (11%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0); catalogued as rs754721080, COSV57789565; called by muse, mutect2, varscan2
- MUC6 | c.6812C>T p.S2271L | Missense Mutation (SNP) | VAF 27/196 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.006); catalogued as COSV70144716; called by muse, mutect2, varscan2
- MVB12B | c.662+2T>C p.X221_splice | Splice Site (SNP) | VAF 23/138 reads (17%) | catalogued as COSV63259233; called by muse, varscan2
- MXRA5 | c.6484G>T p.G2162* | Nonsense Mutation (SNP) | VAF 9/37 reads (24%) | catalogued as COSV99479854; called by muse, mutect2, varscan2
- MYH7 | c.4259G>T p.R1420L | Missense Mutation (SNP) | VAF 27/148 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as CM117575, COSV62518491, COSV62521016; called by muse, mutect2, varscan2
- MYH9 | c.1201G>A p.V401I | Missense Mutation (SNP) | VAF 26/176 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs369581570, COSV53389057; called by muse, mutect2, varscan2
- MYO5A | c.2315G>A p.R772Q | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.135); catalogued as rs185892206, COSV62562066; called by muse, mutect2, varscan2
- MYO6 | c.2837G>A p.R946H | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs781754117, COSV64119885; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYORG | c.1610C>T p.A537V | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.352); catalogued as COSV52627068; called by muse, mutect2, varscan2
- NCALD | c.319A>G p.M107V | Missense Mutation (SNP) | VAF 30/189 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.205); catalogued as rs775815002, COSV55273609; called by muse, mutect2, varscan2
- NCAPD2 | c.263T>C p.V88A | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.163); catalogued as COSV59700749; called by muse, mutect2, varscan2
- NCOA2 | c.4070C>T p.A1357V | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.089); catalogued as rs549428140, COSV51220650; called by muse, mutect2
- NCOA6 | c.3247C>T p.Q1083* | Nonsense Mutation (SNP) | VAF 19/148 reads (13%) | catalogued as COSV62862917; called by muse, mutect2, varscan2
- NCOA6 | c.2938C>T p.Q980* | Nonsense Mutation (SNP) | VAF 19/107 reads (18%) | catalogued as COSV62865389; called by muse, mutect2, varscan2
- NCOA7 | c.209del p.K70Rfs*7 | Frame Shift Del (DEL) | VAF 18/106 reads (17%) | catalogued as rs749319230; called by mutect2, varscan2
- NDST4 | c.1225C>T p.H409Y | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.057); catalogued as rs374331319; called by muse, mutect2
- NEDD9 | c.526G>A p.V176I | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs773292318, COSV65158811; called by muse, mutect2
- NFASC | c.1345C>T p.R449W (on ENST00000339876 / NM_001378329.1; = p.R460W on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.775); catalogued as rs184631101; called by mutect2, varscan2
- NGDN | c.583C>T p.R195* | Nonsense Mutation (SNP) | VAF 17/72 reads (24%) | catalogued as rs956675034, COSV68142582; called by muse, mutect2, varscan2
- NIM1K | c.898C>T p.R300* | Nonsense Mutation (SNP) | VAF 24/107 reads (22%) | catalogued as rs780003257, COSV100390344, COSV58143225; called by muse, mutect2, varscan2
- NISCH | c.2299G>A p.D767N | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.15); catalogued as COSV61901030; called by muse, mutect2, varscan2
- NKX3-2 | c.527C>T p.A176V | Missense Mutation (SNP) | VAF 4/47 reads (9%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs1431941324, COSV66711639; called by muse, mutect2
- NLGN3 | c.359C>T p.P120L | Missense Mutation (SNP) | VAF 17/98 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62444215; called by muse, mutect2, varscan2
- NOTCH4 | c.4498C>T p.R1500C | Missense Mutation (SNP) | VAF 49/242 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.115); catalogued as COSV66681961; called by muse, mutect2, varscan2
- NOVA2 | c.1355C>T p.T452M | Missense Mutation (SNP) | VAF 35/190 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54358515; called by muse, mutect2, varscan2
- NPY2R | c.245G>A p.R82H | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.037); catalogued as rs755838016, COSV61527886, COSV61528318; called by muse, mutect2, varscan2
- NRF1 | c.353C>T p.T118M | Missense Mutation (SNP) | VAF 13/96 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.459); catalogued as COSV56210900; called by muse, mutect2, varscan2
- NRG1 | c.1517C>T p.A506V (on ENST00000405005 / NM_013964.5; = p.A511V on NM_013956.5) | Missense Mutation (SNP) | VAF 15/97 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0.015); catalogued as rs572301736, COSV55166073; called by muse, mutect2, varscan2
- NTF3 | c.368A>G p.Y123C | Missense Mutation (SNP) | VAF 25/127 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.282); catalogued as COSV58417889; called by muse, mutect2, varscan2
- NTNG1 | c.1524C>A p.C508* (on ENST00000370068 / NM_001113226.3; = p.C407* on NM_014917.4 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 8/40 reads (20%) | catalogued as COSV64274829; called by muse, mutect2
- NUDT18 | c.595G>A p.A199T | Missense Mutation (SNP) | VAF 14/87 reads (16%) | SIFT tolerated (0.35); PolyPhen benign (0.015); catalogued as rs747133315, COSV57159223, COSV57161033; called by muse, mutect2, varscan2
- NUMA1 | c.5295del p.K1766Rfs*2 | Frame Shift Del (DEL) | VAF 4/34 reads (12%) | catalogued as rs1207322636, COSV52621264; called by mutect2, pindel, varscan2
- NXPE4 | c.329C>T p.T110M | Missense Mutation (SNP) | VAF 34/172 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.223); catalogued as rs201549180; called by muse, mutect2, varscan2
- OBSL1 | c.4274A>G p.D1425G | Missense Mutation (SNP) | VAF 32/161 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV54707547; called by muse, mutect2, varscan2
- ODF1 | c.88G>A p.E30K | Missense Mutation (SNP) | VAF 32/205 reads (16%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.959); catalogued as rs770707514, COSV53432584; called by muse, mutect2, varscan2
- OGFRL1 | c.1101del p.V368Wfs*36 | Frame Shift Del (DEL) | VAF 11/68 reads (16%) | catalogued as rs1561951813; called by mutect2, pindel, varscan2
- OLFML1 | c.641A>G p.Q214R | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.133); catalogued as COSV55079092; called by muse, mutect2, varscan2
- OR14C36 | c.315del p.F105Lfs*28 | Frame Shift Del (DEL) | VAF 13/65 reads (20%) | catalogued as rs761899382; called by mutect2, varscan2
- OR1D5 | c.554T>G p.L185R | Missense Mutation (SNP) | VAF 5/57 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV73859541; called by muse, mutect2
- OR2A7 | c.532del p.C178Vfs*37 | Frame Shift Del (DEL) | VAF 15/130 reads (12%) | catalogued as rs749245232; called by mutect2, pindel, varscan2
- OR2G6 | c.854del p.L285* | Frame Shift Del (DEL) | VAF 6/52 reads (12%) | catalogued as COSV58573794; called by mutect2, pindel, varscan2
- OR2T4 | c.636A>C p.E212D | Missense Mutation (SNP) | VAF 19/218 reads (9%) | SIFT tolerated (0.09); PolyPhen probably damaging (1); catalogued as COSV63544001; called by muse, mutect2
- OR5AU1 | c.338A>G p.Y113C | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.04); catalogued as rs1035002031, COSV58615825; called by muse, mutect2, varscan2
- OR5F1 | c.635T>G p.L212R | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV53547290; called by muse, mutect2, varscan2
- OR5M3 | c.695G>T p.R232M | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV56566878, COSV56567421; called by muse, mutect2, varscan2
- OR7E24 | c.504del p.F168Lfs*12 | Frame Shift Del (DEL) | VAF 13/53 reads (25%) | catalogued as rs1031417078; called by mutect2, pindel, varscan2
- OSBP2 | c.613G>A p.V205M | Missense Mutation (SNP) | VAF 24/152 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV60244937; called by muse, mutect2, varscan2
- OSBPL10 | c.2165G>A p.R722Q | Missense Mutation (SNP) | VAF 22/144 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.049); catalogued as rs749477578, COSV67341192; called by muse, mutect2, varscan2
- OSCAR | c.94T>C p.S32P | Missense Mutation (SNP) | VAF 17/81 reads (21%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.921); catalogued as COSV52927923; called by muse, mutect2, varscan2
- P4HB | c.1160del p.N387Tfs*118 | Frame Shift Del (DEL) | VAF 10/48 reads (21%) | catalogued as rs763394045; called by mutect2, varscan2
- P4HB | c.949C>T p.L317F | Missense Mutation (SNP) | VAF 14/114 reads (12%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.695); catalogued as COSV58942138; called by muse, mutect2, varscan2
- PANX2 | c.1789G>A p.A597T | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); catalogued as rs759648297, COSV50301192; called by muse, mutect2, varscan2
- PAX6 | c.357C>T p.S119= | Splice Region (SNP) | VAF 13/69 reads (19%) | catalogued as rs121907928, CD082176, CM013024, CM993965, COSV53794419, COSV99570036; called by muse, mutect2, varscan2
- PBRM1 | c.773del p.N258Mfs*25 | Frame Shift Del (DEL) | VAF 6/72 reads (8%) | catalogued as COSV56262297; called by mutect2, pindel
- PBXIP1 | c.493C>T p.R165W | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.017); catalogued as rs372020762; called by muse, mutect2, varscan2
- PCDH17 | c.3378G>T p.R1126S | Missense Mutation (SNP) | VAF 53/268 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.879); catalogued as COSV64971679; called by muse, mutect2, varscan2
- PCDH7 | c.1667C>T p.T556M | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.985); catalogued as rs1486124132, COSV62340747; called by muse, mutect2, varscan2
- PCDHA12 | c.1973C>T p.A658V | Missense Mutation (SNP) | VAF 12/95 reads (13%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.036); catalogued as rs782657623, COSV56494440; called by muse, mutect2, varscan2
- PCDHA7 | c.1730T>C p.V577A | Missense Mutation (SNP) | VAF 37/197 reads (19%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.009); catalogued as COSV65345323; called by muse, mutect2, varscan2
- PCDHA8 | c.1552T>C p.Y518H | Missense Mutation (SNP) | VAF 57/354 reads (16%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.406); catalogued as COSV65323974, COSV65325269, COSV65328684; called by muse, mutect2, varscan2
- PCDHB11 | c.1588C>T p.R530C | Missense Mutation (SNP) | VAF 50/272 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.226); catalogued as rs782123077, COSV61311634; called by muse, mutect2, varscan2
- PCDHB16 | c.2254G>A p.E752K | Missense Mutation (SNP) | VAF 38/225 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.675); catalogued as COSV53357560; called by muse, mutect2, varscan2
- PCDHB2 | c.122C>T p.T41M | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.41); catalogued as rs1554271108, COSV52034436; called by muse, mutect2, varscan2
- PCDHB3 | c.331C>T p.Q111* | Nonsense Mutation (SNP) | VAF 25/111 reads (23%) | catalogued as COSV50588798; called by muse, mutect2, varscan2
- PCDHB3 | c.1879G>A p.A627T | Missense Mutation (SNP) | VAF 43/248 reads (17%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.026); catalogued as rs376298783, COSV50574744; called by muse, mutect2, varscan2
- PCDHGC5 | c.1733G>A p.R578H | Missense Mutation (SNP) | VAF 16/96 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.961); catalogued as rs774983500, COSV52757561; called by muse, varscan2
- PCGF3 | c.53G>A p.R18H | Missense Mutation (SNP) | VAF 21/126 reads (17%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.72); catalogued as rs200875455; called by muse, mutect2, varscan2
- PCNT | c.7030G>A p.G2344S | Missense Mutation (SNP) | VAF 16/98 reads (16%) | SIFT tolerated (0.31); PolyPhen benign (0.166); catalogued as rs781579296, COSV64026945; called by muse, mutect2, varscan2
- PCNX3 | c.3746T>G p.I1249S | Missense Mutation (SNP) | VAF 17/87 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV63138382; called by muse, mutect2, varscan2
- PCNX4 | c.1591C>T p.R531C (on ENST00000406854 / NM_001330177.2; = p.R297C on NM_022495.5) | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as rs773266496, COSV58303323; called by muse, mutect2, varscan2
- PDE4D | c.131G>A p.R44H | Missense Mutation (SNP) | VAF 23/113 reads (20%) | SIFT tolerated, low confidence (0.13); PolyPhen probably damaging (0.984); catalogued as rs774486077, COSV72353481, COSV72355966; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PDE4DIP | c.1571G>A p.R524H | Missense Mutation (SNP) | VAF 29/169 reads (17%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.984); catalogued as rs782310936, COSV57671479; called by mutect2, varscan2
- PDGFRA | c.1289G>A p.G430E | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT tolerated (0.69); PolyPhen benign (0.006); catalogued as rs202072966, COSV57265687; called by muse, mutect2, varscan2
- PDIA3 | c.871C>A p.L291M | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.458); catalogued as COSV100295389; called by muse, mutect2, varscan2
- PDLIM4 | c.454G>A p.E152K | Missense Mutation (SNP) | VAF 66/252 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.078); catalogued as rs368514608; called by muse, mutect2, varscan2
- PDLIM5 | c.971G>A p.R324Q | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as rs115018620, COSV58749594; called by muse, mutect2, varscan2
- PDP2 | c.920G>A p.R307H | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT tolerated (0.56); PolyPhen benign (0.005); catalogued as rs927918302, COSV61240836; called by muse, mutect2, varscan2
- PDSS1 | c.926T>C p.V309A | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.326); catalogued as COSV66059508; called by muse, mutect2, varscan2
- PDZD2 | c.308dup p.K104Qfs*38 | Frame Shift Ins (INS) | VAF 15/101 reads (15%) | catalogued as rs750970663; called by mutect2, varscan2
- PHF23 | c.82C>T p.R28W | Missense Mutation (SNP) | VAF 17/95 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.727); catalogued as COSV50037190; called by muse, mutect2, varscan2
- PHLPP1 | c.4196C>T p.A1399V | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV53032294; called by muse, mutect2
- PIWIL4 | c.739G>A p.A247T | Missense Mutation (SNP) | VAF 21/140 reads (15%) | SIFT tolerated (0.74); PolyPhen benign (0.005); catalogued as rs770456343, COSV54410507; called by muse, mutect2, varscan2
- PLEC | c.10102C>T p.R3368C (on ENST00000322810 / NM_201380.4; = p.R3258C on NM_000445.5) | Missense Mutation (SNP) | VAF 18/132 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.353); catalogued as rs781821437, COSV59656440; called by muse, mutect2, varscan2
- PLEKHF2 | c.387T>G p.C129W | Missense Mutation (SNP) | VAF 27/122 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59541800; called by muse, mutect2, varscan2
- PLG | c.2304G>T p.E768D | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT tolerated (0.6); PolyPhen benign (0.003); catalogued as COSV57518026; called by muse, mutect2, varscan2
- PNLIPRP3 | c.928-2A>G p.X310_splice | Splice Site (SNP) | VAF 8/41 reads (20%) | catalogued as COSV65048852; called by muse, mutect2, varscan2
- POC1A | c.317T>C p.V106A | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV56592229; called by muse, mutect2, varscan2
- POLDIP3 | c.353G>A p.R118Q | Missense Mutation (SNP) | VAF 33/165 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs374659326; called by muse, mutect2, varscan2
- POLQ | c.6193C>T p.Q2065* | Nonsense Mutation (SNP) | VAF 8/69 reads (12%) | catalogued as COSV51755891; called by muse, mutect2
- POLRMT | c.3359C>T p.P1120L | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs772321080, COSV52116184, COSV99241669; called by muse, mutect2, varscan2
- POM121 | c.3683C>T p.A1228V (on ENST00000434423; = p.A963V on NM_172020.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.752); catalogued as rs377106663; called by muse, mutect2
- PPARD | c.337C>T p.R113C | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs201653737, COSV61099768; called by muse, mutect2, varscan2
- PPP1R3A | c.1773G>A p.W591* | Nonsense Mutation (SNP) | VAF 13/116 reads (11%) | catalogued as COSV52886116; called by muse, mutect2, varscan2
- PPP3R2 | c.25G>A p.A9T | Missense Mutation (SNP) | VAF 18/115 reads (16%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV62455723; called by muse, mutect2, varscan2
- PRDM13 | c.2056G>T p.V686L | Missense Mutation (SNP) | VAF 28/93 reads (30%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.775); catalogued as rs754415402, COSV100980428, COSV65030257; called by muse, mutect2, varscan2
- PRDM16 | c.1630G>A p.D544N | Missense Mutation (SNP) | VAF 35/163 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.343); catalogued as COSV54597242; called by muse, mutect2, varscan2
- PRDM16 | c.2214C>A p.Y738* | Nonsense Mutation (SNP) | VAF 23/134 reads (17%) | catalogued as COSV54597251; called by muse, mutect2, varscan2
- PRDM2 | c.1498C>T p.R500W | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1286941974, COSV52450101; called by muse, mutect2, varscan2
- PREX2 | c.119G>A p.G40D | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.721); catalogued as COSV55781887; called by muse, mutect2, varscan2
- PREX2 | c.1324G>A p.G442R | Missense Mutation (SNP) | VAF 26/83 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV55781902; called by muse, mutect2, varscan2
- PRKAR2B | c.1084G>A p.A362T | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.962); catalogued as COSV55925843; called by muse, mutect2, varscan2
- PRKD1 | c.2520+2T>C p.X840_splice | Splice Site (SNP) | VAF 4/18 reads (22%) | catalogued as rs1448609389, COSV59575528; called by muse, mutect2, varscan2
- PRKDC | c.6165C>A p.S2055R | Missense Mutation (SNP) | VAF 23/203 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.784); catalogued as COSV58045407, COSV58057057; called by muse, mutect2, varscan2
- PRMT3 | c.1417C>T p.P473S | Missense Mutation (SNP) | VAF 19/178 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.72); catalogued as rs972394498, COSV58178490; called by muse, mutect2
- PRR14 | c.1289A>G p.Q430R | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as COSV54912584; called by muse, mutect2, varscan2
- PRR19 | c.577C>T p.R193W | Missense Mutation (SNP) | VAF 20/88 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as rs368156714, COSV56626166; called by muse, mutect2, varscan2
- PRSS3 | c.316G>T p.V106F (on ENST00000361005 / NM_007343.4; = p.V214F on NM_002771.3) | Missense Mutation (SNP) | VAF 20/135 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61557449; called by muse, mutect2, varscan2
- PRTG | c.3167del p.F1056Sfs*30 | Frame Shift Del (DEL) | VAF 7/36 reads (19%) | catalogued as rs768325902, COSV101221331; called by mutect2, varscan2
- PSMA4 | c.315A>G p.I105M | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT tolerated (0.39); PolyPhen benign (0.286); catalogued as COSV50384886; called by muse, mutect2, varscan2
- PSMD12 | c.431G>A p.R144Q | Missense Mutation (SNP) | VAF 7/75 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1465093867, COSV62065574, COSV62066211; called by muse, mutect2
- PTCHD1 | c.232C>T p.R78C | Missense Mutation (SNP) | VAF 19/93 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.827); catalogued as COSV65061507; called by muse, mutect2, varscan2
- PTK2B | c.1264C>T p.R422C | Missense Mutation (SNP) | VAF 37/219 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs769474828, COSV57760017; called by muse, mutect2, varscan2
- PTPN3 | c.632C>T p.A211V | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs193920798, COSV52701715; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PTPRG | c.3198A>C p.R1066S | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV99877431; called by mutect2, varscan2
- RAD50 | c.3554G>A p.R1185Q | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs747603489, COSV54753933; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RAPGEF3 | c.1451C>A p.P484H (on ENST00000389212; = p.P442H on NM_006105.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV50215375; called by muse, mutect2, varscan2
- RAPH1 | c.2294del p.P765Hfs*19 | Frame Shift Del (DEL) | VAF 16/86 reads (19%) | catalogued as rs760908242; called by mutect2, varscan2
- RASGEF1B | c.967del p.T323Lfs*5 | Frame Shift Del (DEL) | VAF 8/44 reads (18%) | catalogued as rs765006689; called by mutect2, varscan2
- RBM39 | c.482C>T p.A161V | Missense Mutation (SNP) | VAF 13/113 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs1451894009, COSV53616150; called by muse, mutect2, varscan2
- RBM42 | c.1348C>T p.R450C | Missense Mutation (SNP) | VAF 15/108 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.009); catalogued as COSV52898179; called by muse, mutect2, varscan2
- RBM6 | c.2495A>G p.E832G | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs780711178, COSV56484832; called by muse, mutect2, varscan2
- RBMS1 | c.536C>T p.T179I | Missense Mutation (SNP) | VAF 19/82 reads (23%) | SIFT tolerated (0.24); PolyPhen benign (0.024); catalogued as rs1482168701, COSV62354625; called by muse, mutect2, varscan2
- RDX | c.1412del p.P471Lfs*35 | Frame Shift Del (DEL) | VAF 16/118 reads (14%) | catalogued as COSV100563010; called by pindel, varscan2
- RECK | c.2054dup p.N685Kfs*16 | Frame Shift Ins (INS) | VAF 11/43 reads (26%) | catalogued as rs935356864; called by mutect2, varscan2
- RGL3 | c.1889G>A p.R630Q | Missense Mutation (SNP) | VAF 19/116 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.889); catalogued as rs1419950017, COSV66507737; called by muse, mutect2, varscan2
- RGS12 | c.3534del p.K1178Nfs*32 | Frame Shift Del (DEL) | VAF 8/39 reads (21%) | catalogued as rs753542639, COSV58750063; called by mutect2, varscan2
- RHBDF1 | c.40C>T p.R14C | Missense Mutation (SNP) | VAF 25/117 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.912); catalogued as rs369963935; called by muse, mutect2, varscan2
- RHOXF2 | c.359G>A p.R120H | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.062); catalogued as rs781886657, COSV65047714, COSV65048009; called by mutect2, varscan2
- RLBP1 | c.472G>A p.V158I | Missense Mutation (SNP) | VAF 11/116 reads (9%) | SIFT tolerated (0.8); PolyPhen benign (0.025); catalogued as COSV51528603; called by muse, mutect2
- RMC1 | c.484G>A p.E162K | Missense Mutation (SNP) | VAF 19/121 reads (16%) | SIFT tolerated (0.36); PolyPhen benign (0.086); catalogued as rs1310886027, COSV52570676; called by muse, mutect2, varscan2
- RNF145 | c.1649C>T p.T550M (on ENST00000424310 / NM_001199383.2; = p.T578M on NM_144726.2) | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.876); catalogued as rs1008698102, COSV50868034; called by muse, mutect2, varscan2
- RNF182 | c.353T>C p.L118P | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.766); catalogued as rs1205963574, COSV70369482, COSV70369882; called by muse, mutect2, varscan2
- RNF43 | c.1976del p.G659Vfs*41 | Frame Shift Del (DEL) | VAF 38/148 reads (26%) | catalogued as rs755128667, COSV68457540; called by mutect2, pindel, varscan2
- RNH1 | c.988T>C p.C330R | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62251291; called by muse, mutect2, varscan2
- RPS6KB1 | c.1540A>G p.I514V | Missense Mutation (SNP) | VAF 14/100 reads (14%) | SIFT tolerated, low confidence (0.65); PolyPhen benign (0.005); catalogued as COSV56677976; called by muse, mutect2, varscan2
- RPS6KC1 | c.658C>T p.R220W | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.852); catalogued as rs768437981, COSV65300916; called by muse, mutect2, varscan2
- RSPH9 | c.19C>A p.L7M | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT tolerated (0.22); PolyPhen benign (0.006); catalogued as COSV64665330; called by muse, mutect2, varscan2
- RXFP1 | c.136C>T p.H46Y | Missense Mutation (SNP) | VAF 17/129 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV57052413; called by muse, mutect2, varscan2
- RXFP1 | c.431A>G p.D144G | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.005); catalogued as COSV57052424; called by muse, mutect2
- RYR1 | c.2269C>A p.R757S | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT tolerated (0.09); PolyPhen probably damaging (1); catalogued as COSV100615230, COSV62102337; called by muse, mutect2, varscan2
- RYR1 | c.7036G>A p.V2346M | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as rs193922799, CM043566, COSV62102343; ClinVar: not provided; called by muse, mutect2, varscan2
- S1PR3 | c.679C>T p.R227C | Missense Mutation (SNP) | VAF 20/85 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs886673716, COSV63980848; called by muse, mutect2, varscan2
- SAMD4A | c.829C>T p.R277* | Nonsense Mutation (SNP) | VAF 60/326 reads (18%) | catalogued as rs1461067531, COSV51883940; called by muse, mutect2, varscan2
- SBF1 | c.5408C>A p.P1803H | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.458); catalogued as COSV53295505; called by muse, mutect2
- SBNO1 | c.1813T>C p.C605R (on ENST00000420886; = p.C604R on NM_018183.5) | Missense Mutation (SNP) | VAF 27/155 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV57343180; called by muse, mutect2, varscan2
- SCAMP2 | c.637G>A p.D213N | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.858); catalogued as rs369338474; called by mutect2, varscan2
- SCLT1 | c.1620del p.A541Pfs*3 | Frame Shift Del (DEL) | VAF 8/66 reads (12%) | catalogued as rs760494753; called by mutect2, varscan2
- SCUBE1 | c.1549G>T p.D517Y | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.396); catalogued as COSV62613888; called by muse, mutect2, varscan2
- SDK1 | c.2404C>T p.R802C | Missense Mutation (SNP) | VAF 26/150 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.863); catalogued as rs746030448, COSV67377251; called by muse, mutect2, varscan2
- SDK1 | c.6259C>T p.P2087S | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV67377257; called by muse, mutect2, varscan2
- SDK2 | c.5861G>A p.R1954Q | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.383); catalogued as rs373850295; called by muse, mutect2, varscan2
- SEC16B | c.1299del p.S434Vfs*29 | Frame Shift Del (DEL) | VAF 8/43 reads (19%) | catalogued as rs768388757; called by mutect2, pindel, varscan2
- SECTM1 | c.634C>A p.P212T | Missense Mutation (SNP) | VAF 14/87 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.468); catalogued as COSV53939936; called by muse, mutect2, varscan2
- SEL1L3 | c.641C>A p.P214H | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53538483; called by muse, mutect2, varscan2
- SEPHS2 | c.1226A>G p.K409R | Missense Mutation (SNP) | VAF 21/92 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.098); catalogued as COSV72100783; called by muse, mutect2, varscan2
- SERINC1 | c.932A>C p.Q311P | Missense Mutation (SNP) | VAF 24/137 reads (18%) | SIFT tolerated (0.23); PolyPhen benign (0.014); catalogued as COSV60102398; called by muse, mutect2, varscan2
- SH2D4B | c.382C>T p.R128W | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.073); catalogued as rs1425235481, COSV57897746; called by muse, mutect2, varscan2
- SH3TC1 | c.3127G>A p.E1043K | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.815); catalogued as rs755795530, COSV55284022; called by muse, mutect2
- SHC1 | c.1310G>A p.R437Q (on ENST00000368445 / NM_183001.5; = p.R328Q on NM_003029.5) | Missense Mutation (SNP) | VAF 21/122 reads (17%) | SIFT tolerated (0.41); PolyPhen benign (0.417); catalogued as rs376945597; called by muse, mutect2, varscan2
- SHC4 | c.494T>G p.L165R | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT tolerated (0.48); PolyPhen benign (0.36); catalogued as COSV60114004; called by muse, mutect2, varscan2
- SHROOM4 | c.1450T>C p.S484P | Missense Mutation (SNP) | VAF 7/144 reads (5%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as COSV56792303; called by muse, mutect2
- SI | c.4534A>T p.I1512F | Missense Mutation (SNP) | VAF 22/109 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV52286769; called by muse, mutect2, varscan2
- SIAH2 | c.842G>A p.R281H | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.983); catalogued as rs765846031, COSV57261996; called by muse, mutect2, varscan2
- SIGLEC8 | c.1381C>T p.Q461* | Nonsense Mutation (SNP) | VAF 24/99 reads (24%) | catalogued as COSV58474549; called by muse, mutect2, varscan2
- SLC14A2 | c.85A>G p.S29G | Missense Mutation (SNP) | VAF 18/110 reads (16%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.015); catalogued as COSV54910811; called by muse, mutect2, varscan2
- SLC22A11 | c.1288C>T p.R430C | Missense Mutation (SNP) | VAF 20/109 reads (18%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.677); catalogued as COSV57253967; called by muse, mutect2, varscan2
- SLC25A18 | c.926G>A p.R309H | Missense Mutation (SNP) | VAF 33/168 reads (20%) | SIFT tolerated (0.53); PolyPhen benign (0.001); catalogued as rs140365489, COSV53657156; called by muse, mutect2, varscan2
- SLC25A25 | c.1410A>G p.*470Wext*38 | Nonstop Mutation (SNP) | VAF 28/153 reads (18%) | catalogued as COSV66086527; called by muse, mutect2, varscan2
- SLC27A4 | c.1804C>T p.R602W | Missense Mutation (SNP) | VAF 25/138 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.677); catalogued as rs758250643, COSV55960645; called by muse, mutect2, varscan2
- SLC2A5 | c.779C>T p.A260V | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.31); PolyPhen benign (0.015); catalogued as rs770313806, COSV66237368; called by muse, mutect2
- SLC35F5 | c.578G>A p.R193H | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.987); catalogued as rs776435612, COSV55519170, COSV99830170; called by muse, mutect2, varscan2
- SLC39A4 | c.1931A>G p.D644G (on ENST00000301305 / NM_001374839.1; = p.D619G on NM_017767.3) | Missense Mutation (SNP) | VAF 33/237 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.062); catalogued as COSV52779790; called by muse, mutect2, varscan2
- SLC3A2 | c.899del p.K300Rfs*31 | Frame Shift Del (DEL) | VAF 12/51 reads (24%) | catalogued as rs760089491; called by mutect2, varscan2
- SLC45A4 | c.1343T>C p.L448P (on ENST00000517878 / NM_001286646.2; = p.L397P on NM_001080431.2) | Missense Mutation (SNP) | VAF 19/128 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0.07); catalogued as COSV50145890; called by muse, mutect2, varscan2
- SLC49A3 | c.809T>C p.L270P (on ENST00000404286 / NM_001294341.2; = p.L269P on NM_032219.4) | Missense Mutation (SNP) | VAF 26/132 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59140975; called by muse, mutect2, varscan2
- SLC4A3 | c.2675C>T p.T892M | Missense Mutation (SNP) | VAF 19/93 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1398058468, COSV56095381; called by muse, mutect2, varscan2
- SLC5A9 | c.1148G>A p.R383Q | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs775516581, COSV52584316, COSV99362058; called by muse, mutect2, varscan2
- SLC7A14 | c.2099A>G p.D700G | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.239); catalogued as COSV51585219; called by muse, mutect2, varscan2
- SLC7A14 | c.1067C>T p.P356L | Missense Mutation (SNP) | VAF 16/106 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs371104588; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLITRK5 | c.2830G>A p.D944N | Missense Mutation (SNP) | VAF 46/176 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV61523961; called by muse, mutect2, varscan2
- SLITRK6 | c.2158A>C p.S720R | Missense Mutation (SNP) | VAF 14/298 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0.188); catalogued as COSV68389664, COSV68390670; called by muse, mutect2
- SNRPA | c.425C>T p.P142L | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT tolerated (0.16); PolyPhen benign (0.073); catalogued as rs775580802, COSV54681816; called by muse, mutect2, varscan2
- SORCS3 | c.611C>T p.S204L | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.859); catalogued as COSV100865158, COSV63815498; called by muse, mutect2, varscan2
- SORT1 | c.931C>T p.R311C | Missense Mutation (SNP) | VAF 26/94 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.868); catalogued as rs1281587187, COSV56667767; called by muse, mutect2, varscan2
- SOX21 | c.122G>A p.R41H | Missense Mutation (SNP) | VAF 19/148 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.586); catalogued as COSV65375397; called by muse, mutect2, varscan2
- SOX7 | c.254C>T p.A85V | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs765208739, COSV58731168; called by muse, mutect2, varscan2
- SPATA18 | c.998G>A p.R333Q | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as rs768941721, COSV54646937; called by muse, mutect2
- SPATA6 | c.1154del p.N385Mfs*3 | Frame Shift Del (DEL) | VAF 9/70 reads (13%) | catalogued as rs1437710788; called by mutect2, pindel, varscan2
- SPECC1 | c.908del p.N303Tfs*63 | Frame Shift Del (DEL) | VAF 28/127 reads (22%) | catalogued as COSV54965656; called by mutect2, varscan2
- SPEM2 | c.389G>A p.R130H | Missense Mutation (SNP) | VAF 24/156 reads (15%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs747765542, COSV60366376; called by muse, mutect2, varscan2
- SPG11 | c.2849del p.L950Wfs*13 | Frame Shift Del (DEL) | VAF 12/54 reads (22%) | catalogued as CD166713; called by mutect2, pindel, varscan2
- SPG21 | c.487del p.I163* | Frame Shift Del (DEL) | VAF 29/171 reads (17%) | catalogued as rs970163893; called by mutect2, pindel, varscan2
- SPG21 | c.109G>A p.A37T | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT tolerated (0.41); PolyPhen benign (0.055); catalogued as rs142452716, COSV99200183; called by muse, mutect2, varscan2
- SPI1 | c.44del p.P15Lfs*171 | Frame Shift Del (DEL) | VAF 5/33 reads (15%) | catalogued as rs779746068; called by mutect2, pindel, varscan2
- SRF | c.685G>A p.D229N | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.71); catalogued as rs1477867635, COSV54839185; called by muse, mutect2, varscan2
- SRGN | c.293T>C p.F98S | Missense Mutation (SNP) | VAF 14/89 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54344443; called by muse, mutect2, varscan2
- SRSF5 | c.415G>A p.A139T | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.545); catalogued as COSV53683026; called by muse, mutect2, varscan2
- STARD13 | c.1868G>A p.R623H (on ENST00000336934 / NM_001243476.3; = p.R505H on NM_052851.3) | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); catalogued as rs1566003840, COSV55233024; called by muse, mutect2, varscan2
- STK10 | c.2101A>C p.K701Q | Missense Mutation (SNP) | VAF 26/179 reads (15%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.987); catalogued as COSV51576014; called by muse, mutect2, varscan2
- STOX2 | c.589G>A p.D197N | Missense Mutation (SNP) | VAF 25/121 reads (21%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.981); catalogued as rs776429999, COSV57853793; called by muse, mutect2, varscan2
- STX7 | c.250-1G>A p.X84_splice | Splice Site (SNP) | VAF 17/89 reads (19%) | catalogued as COSV63398920; called by muse, mutect2, varscan2
- SUMF1 | c.892G>A p.A298T | Missense Mutation (SNP) | VAF 27/129 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.152); catalogued as rs1249221556, COSV55994224; called by muse, mutect2, varscan2
- SUPT6H | c.74G>A p.R25Q | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.019); catalogued as rs746505120, COSV58928879; called by mutect2, varscan2
- SYNE1 | c.24347C>T p.A8116V (on ENST00000367255 / NM_182961.4; = p.A8045V on NM_033071.3) | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.975); catalogued as rs781159250, COSV55025559; called by muse, mutect2, varscan2
- SYNE1 | c.19960T>C p.F6654L (on ENST00000367255 / NM_182961.4; = p.F6583L on NM_033071.3) | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT tolerated (0.86); PolyPhen benign (0.003); catalogued as COSV55025587; called by muse, mutect2, varscan2
- SYNE4 | c.224C>T p.P75L | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.031); catalogued as rs754761165, COSV53325189, COSV53325739; called by muse, mutect2, varscan2
- SZT2 | c.2075G>T p.R692L | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.559); catalogued as COSV100987744; called by mutect2, varscan2
- TAS1R2 | c.868C>T p.R290C | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.975); catalogued as rs766879604, COSV64744538; called by muse, mutect2, varscan2
- TAS2R41 | c.448dup p.W150Lfs*13 | Frame Shift Ins (INS) | VAF 10/52 reads (19%) | catalogued as rs753168244; called by mutect2, varscan2
- TBC1D23 | c.1947del p.K649Nfs*18 (on ENST00000394144 / NM_001199198.3; = p.K634Nfs*18 on NM_018309.5) | Frame Shift Del (DEL) | VAF 17/38 reads (45%) | catalogued as rs747637295, COSV61367528; called by mutect2, varscan2
- TBC1D9B | c.3485C>T p.T1162M (on ENST00000356834 / NM_198868.3; = p.T1145M on NM_015043.4) | Missense Mutation (SNP) | VAF 21/149 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.514); catalogued as rs372876819; called by muse, mutect2, varscan2
- TBC1D9B | c.1675C>T p.R559C | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs768433157, COSV62282742; called by muse, mutect2, varscan2
- TBP | c.814G>A p.G272S | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.895); catalogued as COSV57832620, COSV57833387; called by muse, mutect2
- TCERG1 | c.2870del p.K957Rfs*17 | Frame Shift Del (DEL) | VAF 16/80 reads (20%) | catalogued as rs758822980; called by mutect2, varscan2
- TENM1 | c.4384T>C p.Y1462H | Missense Mutation (SNP) | VAF 31/146 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV64436213; called by muse, mutect2, varscan2
- TENM3 | c.323G>T p.R108I | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.097); catalogued as COSV69312715; called by muse, mutect2, varscan2
- TERT | c.320C>A p.A107D | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.47); PolyPhen benign (0.006); catalogued as COSV99721492; called by muse, mutect2, varscan2
- TESK2 | c.668T>C p.M223T | Missense Mutation (SNP) | VAF 28/201 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59154236; called by muse, mutect2, varscan2
- TET2 | c.1982A>G p.H661R | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT tolerated (0.86); PolyPhen benign (0); catalogued as COSV54419453; called by muse, mutect2, varscan2
- TFCP2L1 | c.673C>T p.R225W | Missense Mutation (SNP) | VAF 24/175 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55292626; called by muse, mutect2, varscan2
- TGIF2LX | c.126A>C p.R42S | Missense Mutation (SNP) | VAF 18/92 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV52213888, COSV99383586; called by muse, mutect2, varscan2
- TIAM1 | c.1441G>A p.G481S | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.966); catalogued as rs756834470, COSV54560176; called by muse, mutect2, varscan2
- TIAM2 | c.478del p.R160Efs*14 | Frame Shift Del (DEL) | VAF 9/63 reads (14%) | catalogued as COSV59691458; called by mutect2, pindel, varscan2
- TLN2 | c.3493G>A p.A1165T | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs1037722216, COSV60891750; called by muse, mutect2, varscan2
- TLR7 | c.2446G>T p.G816W | Missense Mutation (SNP) | VAF 16/126 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV66124747; called by muse, mutect2, varscan2
- TMC3 | c.760C>T p.R254C | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs139922591, COSV63923899; called by muse, mutect2
- TMEM104 | c.163A>G p.M55V | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT tolerated (0.17); PolyPhen benign (0.114); catalogued as rs755157238, COSV59110441; called by muse, mutect2, varscan2
- TMEM104 | c.1157G>A p.R386H | Missense Mutation (SNP) | VAF 28/162 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.616); catalogued as rs146415645, COSV59110453; called by muse, mutect2, varscan2
- TMEM52B | c.140T>C p.L47S (on ENST00000381923 / NM_001079815.1; = p.L27S on NM_153022.4) | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53728850; called by muse, mutect2
- TMEM74 | c.407C>A p.P136H | Missense Mutation (SNP) | VAF 15/112 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.437); catalogued as COSV52463853; called by muse, mutect2, varscan2
- TMPRSS11A | c.931A>G p.I311V | Missense Mutation (SNP) | VAF 31/115 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.065); catalogued as rs370630483; called by muse, mutect2, varscan2
- TMPRSS11F | c.436del p.I146Lfs*9 | Frame Shift Del (DEL) | VAF 5/28 reads (18%) | catalogued as rs774592951; called by mutect2, pindel, varscan2
- TNC | c.5020A>G p.T1674A | Missense Mutation (SNP) | VAF 36/163 reads (22%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.728); catalogued as COSV60786790; called by muse, mutect2, varscan2
- TNKS1BP1 | c.5096T>C p.L1699P | Missense Mutation (SNP) | VAF 20/140 reads (14%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.986); catalogued as COSV64101618; called by muse, mutect2, varscan2
- TNKS1BP1 | c.2092G>A p.G698S | Missense Mutation (SNP) | VAF 15/85 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs200365694, COSV64101315; called by muse, mutect2, varscan2
- TP53BP2 | c.35T>C p.L12P | Missense Mutation (SNP) | VAF 40/235 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59070174; called by muse, mutect2, varscan2
- TP63 | c.62+2T>C p.X21_splice | Splice Site (SNP) | VAF 19/138 reads (14%) | catalogued as COSV53211418, COSV53217208; called by muse, mutect2, varscan2
- TPO | c.611del p.P204Rfs*5 | Frame Shift Del (DEL) | VAF 11/63 reads (17%) | catalogued as COSV100219300; called by mutect2, pindel, varscan2
- TPP2 | c.1645G>A p.V549I | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.596); catalogued as rs575735677, COSV65753514; called by muse, mutect2, varscan2
- TPRG1 | c.790C>T p.L264F | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61466465; called by muse, mutect2, varscan2
- TPRN | c.1819G>C p.E607Q | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.829); catalogued as rs754397078, COSV58807562; called by muse, mutect2, varscan2
- TRIM26 | c.1559G>A p.R520Q | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated (0.43); PolyPhen benign (0.011); catalogued as COSV70983211; called by muse, mutect2, varscan2
- TRIM56 | c.1525del p.R509Gfs*23 | Frame Shift Del (DEL) | VAF 25/173 reads (14%) | catalogued as COSV60157516; called by mutect2, pindel, varscan2
- TRIM9 | c.446G>A p.R149H | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV53614552; called by muse, mutect2, varscan2
- TRIO | c.8291A>C p.D2764A | Missense Mutation (SNP) | VAF 29/166 reads (17%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.984); catalogued as COSV59988722, COSV59991106; called by muse, mutect2, varscan2
- TRIP4 | c.180del p.G61Vfs*4 | Frame Shift Del (DEL) | VAF 9/49 reads (18%) | catalogued as rs1446427502; called by mutect2, pindel, varscan2
- TRMT12 | c.1234G>A p.G412R | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.718); catalogued as COSV60777378; called by muse, mutect2, varscan2
- TRRAP | c.6649T>C p.S2217P (on ENST00000359863 / NM_001244580.1; = p.S2199P on NM_003496.3) | Missense Mutation (SNP) | VAF 19/115 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.863); catalogued as COSV62848151; called by muse, mutect2, varscan2
- TSNARE1 | c.838C>T p.R280W | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.353); catalogued as rs374432901; called by muse, mutect2, varscan2
- TSPYL5 | c.406C>A p.P136T | Missense Mutation (SNP) | VAF 15/91 reads (16%) | SIFT tolerated (0.62); PolyPhen benign (0.081); catalogued as COSV59072030; called by muse, mutect2, varscan2
- TSPYL6 | c.299C>T p.A100V | Missense Mutation (SNP) | VAF 24/97 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.024); catalogued as rs1243685150, COSV57816939; called by muse, mutect2
- TSR1 | c.1658A>G p.E553G | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT tolerated (0.34); PolyPhen benign (0.006); catalogued as COSV56785810; called by muse, mutect2, varscan2
- TTC3 | c.2152T>C p.C718R | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100696171; called by muse, varscan2
- TTC7B | c.604A>G p.S202G | Missense Mutation (SNP) | VAF 19/82 reads (23%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.878); catalogued as COSV60634353; called by muse, mutect2, varscan2
- TTF1 | c.1838T>C p.V613A | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT tolerated (0.17); PolyPhen benign (0.036); catalogued as COSV57505430; called by muse, mutect2, varscan2
- TTLL10 | c.1034A>G p.D345G (on ENST00000379289 / NM_001130045.2; = p.D272G on NM_153254.3) | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.077); catalogued as COSV64960346; called by muse, mutect2
- TTN | c.80833A>G p.I26945V (on ENST00000591111; = p.I19521V on NM_003319.4) | Missense Mutation (SNP) | VAF 6/42 reads (14%) | PolyPhen benign (0); catalogued as rs1187128207, COSV60169260; called by muse, mutect2, varscan2
- TTN | c.49255G>A p.V16419I (on ENST00000591111; = p.V8995I on NM_003319.4) | Missense Mutation (SNP) | VAF 23/154 reads (15%) | PolyPhen benign (0.134); catalogued as rs190574498; ClinVar: benign / uncertain significance; called by muse, mutect2, varscan2
- TTN | c.32979G>T p.K10993N (on ENST00000591111; = p.K10066N on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/82 reads (21%) | PolyPhen benign (0.366); catalogued as COSV100635594, COSV60343960; called by muse, mutect2, varscan2
- TTN | c.26572A>G p.T8858A (on ENST00000591111; = p.T7931A on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/129 reads (12%) | PolyPhen benign (0); catalogued as COSV60169301; called by muse, mutect2, varscan2
- TUBG1 | c.866C>T p.T289M | Missense Mutation (SNP) | VAF 23/113 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.476); catalogued as COSV52221679; called by muse, mutect2, varscan2
- TUFM | c.1000C>T p.R334W | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as rs1408118643, CM1312355, COSV57949292; called by muse, mutect2, varscan2
- TUSC3 | c.167T>C p.L56P | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV65883831; called by muse, mutect2, varscan2
- TUT4 | c.3149T>C p.I1050T | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57116305; called by muse, mutect2, varscan2
- UBL4B | c.97C>T p.R33W | Missense Mutation (SNP) | VAF 17/111 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs559740041, COSV61944522; called by muse, mutect2, varscan2
- UBQLN1 | c.1094C>A p.P365H | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.241); catalogued as COSV57408446; called by muse, mutect2
- UBQLN3 | c.1387T>C p.S463P | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV61164700; called by muse, mutect2, varscan2
- UBR5 | c.6360del p.E2121Kfs*28 | Frame Shift Del (DEL) | VAF 23/90 reads (26%) | catalogued as rs763652408; called by mutect2, varscan2
- UGDH | c.214del p.S72Lfs*18 | Frame Shift Del (DEL) | VAF 11/55 reads (20%) | catalogued as rs765734647, COSV57097233; called by mutect2, varscan2
- UNC5D | c.2765T>G p.L922R | Missense Mutation (SNP) | VAF 18/94 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54809257; called by muse, mutect2, varscan2
- USH2A | c.7828C>T p.L2610F | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.771); catalogued as rs1288636636, COSV56325748; called by muse, mutect2, varscan2
- USP1 | c.1985del p.N662Mfs*2 | Frame Shift Del (DEL) | VAF 14/48 reads (29%) | catalogued as rs751218576; ClinVar: not provided; called by mutect2, varscan2
- USP13 | c.1393G>A p.G465S | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT tolerated (0.45); PolyPhen benign (0.418); catalogued as rs61750381, COSV55862837, COSV55867384; called by muse, mutect2, varscan2
- USP24 | c.6271C>T p.R2091W | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as COSV53771367; called by muse, mutect2, varscan2
- USP31 | c.1985T>A p.V662D | Missense Mutation (SNP) | VAF 18/112 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54854049; called by muse, mutect2, varscan2
- USP8 | c.226del p.R76Dfs*36 | Frame Shift Del (DEL) | VAF 13/44 reads (30%) | catalogued as rs1567603601; called by mutect2, pindel, varscan2
- VILL | c.703C>T p.R235C | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.009); catalogued as rs368557605; called by muse, mutect2, varscan2
- VPS13B | c.1646G>A p.G549D | Missense Mutation (SNP) | VAF 14/114 reads (12%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.451); catalogued as rs886062536, COSV62021982; ClinVar: uncertain significance; called by muse, varscan2
- VWA7 | c.2030C>A p.P677H | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.724); catalogued as COSV100992019; called by muse, mutect2
- WDR64 | c.2995G>A p.V999M | Missense Mutation (SNP) | VAF 12/97 reads (12%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as rs755456414, COSV100844158; called by muse, mutect2, varscan2
- WNT3 | c.485C>T p.A162V | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT tolerated (0.81); PolyPhen benign (0.007); catalogued as COSV56645973; called by muse, mutect2, varscan2
- WTAP | c.850C>T p.R284C | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.125); catalogued as rs747375621, COSV100603429; called by muse, mutect2, varscan2
- WTAP | c.851G>A p.R284H | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs771401662, COSV100603431; called by muse, mutect2, varscan2
- WWP2 | c.961C>T p.H321Y | Missense Mutation (SNP) | VAF 23/126 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63125896; called by muse, mutect2, varscan2
- XKRX | c.10G>C p.V4L | Missense Mutation (SNP) | VAF 38/270 reads (14%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.031); catalogued as rs752368088, COSV60708639; called by muse, mutect2, varscan2
- XPO7 | c.193A>G p.T65A | Missense Mutation (SNP) | VAF 4/43 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.199); catalogued as COSV53016889; called by muse, mutect2
- XYLT2 | c.1584del p.G529Afs*78 | Frame Shift Del (DEL) | VAF 20/104 reads (19%) | catalogued as rs779864368; called by mutect2, pindel, varscan2
- YLPM1 | c.3236G>A p.R1079Q | Missense Mutation (SNP) | VAF 15/88 reads (17%) | SIFT tolerated, low confidence (0.2); PolyPhen probably damaging (0.995); catalogued as rs781686745, COSV53115380; called by muse, mutect2, varscan2
- ZAP70 | c.110G>A p.R37H | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1311937867, COSV53854609, COSV53855416; called by muse, mutect2
- ZBTB20 | c.1054G>A p.E352K (on ENST00000474710 / NM_001164342.2; = p.E279K on NM_015642.6 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 24/102 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0.098); catalogued as COSV61856526; called by muse, mutect2, varscan2
- ZC3H12A | c.1635G>T p.R545S | Missense Mutation (SNP) | VAF 14/137 reads (10%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as COSV66104282; called by muse, mutect2, varscan2
- ZC3H13 | c.3958C>T p.Q1320* | Nonsense Mutation (SNP) | VAF 22/86 reads (26%) | catalogued as COSV54457669; called by muse, mutect2
- ZDBF2 | c.5184del p.K1728Nfs*5 | Frame Shift Del (DEL) | VAF 7/39 reads (18%) | catalogued as rs745875253; called by mutect2, varscan2
- ZFHX3 | c.8968G>A p.V2990I | Missense Mutation (SNP) | VAF 27/127 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs757947521, COSV51716544; called by muse, mutect2, varscan2
- ZFP42 | c.215A>G p.Y72C | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.358); catalogued as rs758901164, COSV58818171; called by muse, mutect2, varscan2
- ZGPAT | c.709C>T p.R237C | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as rs145256068; called by muse, mutect2, varscan2
- ZNF182 | c.481G>A p.E161K | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT tolerated (0.22); PolyPhen benign (0.012); catalogued as rs782543305, COSV59358213; called by muse, mutect2, varscan2
- ZNF217 | c.2936A>T p.D979V | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.154); catalogued as COSV56599233; called by muse, mutect2, varscan2
- ZNF285 | c.1039G>A p.D347N | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.023); catalogued as rs202025427, COSV58409715; called by muse, mutect2, varscan2
- ZNF362 | c.596C>T p.A199V | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.491); catalogued as rs1205298949, COSV65031628; called by muse, mutect2, varscan2
- ZNF366 | c.400G>A p.V134M | Missense Mutation (SNP) | VAF 30/197 reads (15%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.031); catalogued as rs778281671, COSV59216893; called by muse, mutect2, varscan2
- ZNF441 | c.1357G>A p.G453R | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.769); catalogued as rs759087202, COSV63540186; called by muse, mutect2, varscan2
- ZNF534 | c.815A>G p.Q272R (on ENST00000332323 / NM_001143939.3; = p.Q259R on NM_001143938.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated (0.63); PolyPhen benign (0.021); catalogued as COSV56519031; called by muse, mutect2
- ZNF536 | c.742G>A p.V248I | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0.013); catalogued as rs528598169, COSV62827760; called by muse, mutect2, varscan2
- ZNF563 | c.542G>A p.R181H | Missense Mutation (SNP) | VAF 24/123 reads (20%) | SIFT tolerated (0.56); PolyPhen benign (0.439); catalogued as rs756158317, COSV53371123; called by muse, mutect2, varscan2
- ZNF587 | c.157T>A p.S53T | Missense Mutation (SNP) | VAF 22/96 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as COSV100299725; called by muse, mutect2, varscan2
- ZNF606 | c.838G>A p.A280T | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV62047740; called by muse, mutect2, varscan2
- ZNF620 | c.845G>A p.C282Y | Missense Mutation (SNP) | VAF 9/88 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58820636; called by muse, mutect2, varscan2
- ZNF644 | c.1570T>C p.Y524H | Missense Mutation (SNP) | VAF 19/98 reads (19%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.96); catalogued as COSV61348709; called by muse, mutect2, varscan2
- ZNF780A | c.545A>G p.Q182R | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.932); catalogued as rs763637995, COSV61815844; called by muse, mutect2
- ZNF80 | c.346C>T p.R116C | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.754); catalogued as rs757877383, COSV57361609; called by muse, mutect2, varscan2
- ZNF99 | c.1667A>T p.K556M | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.915); catalogued as COSV68056068, COSV68056118; called by mutect2, varscan2
- ZNRF3 | c.433C>T p.R145* (on ENST00000544604 / NM_001206998.2; = p.R45* on NM_032173.3) | Nonsense Mutation (SNP) | VAF 3/34 reads (9%) | catalogued as COSV60432649; called by muse, mutect2
- ZP2 | c.1984C>A p.L662M | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as COSV54814975; called by muse, mutect2, varscan2
- ZSCAN30 | c.119A>C p.N40T | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.018); catalogued as COSV60883160; called by muse, mutect2, varscan2
- ZXDC | c.2186del p.K729Sfs*19 | Frame Shift Del (DEL) | VAF 65/480 reads (14%) | catalogued as rs1198185803, COSV60448663; called by mutect2, pindel, varscan2
- ABHD5 | c.23_25del p.V8del | In Frame Del (DEL) | VAF 6/36 reads (17%) | called by mutect2, varscan2
- ACAT1 | c.167del p.L56* | Frame Shift Del (DEL) | VAF 11/75 reads (15%) | called by mutect2, pindel, varscan2
- ADCY10 | c.666del p.N223Ifs*27 | Frame Shift Del (DEL) | VAF 33/142 reads (23%) | called by mutect2, pindel, varscan2
- ADCY6 | c.182del p.P61Lfs*36 | Frame Shift Del (DEL) | VAF 8/65 reads (12%) | called by mutect2, pindel, varscan2
- ADCY9 | c.2229del p.F743Lfs*10 | Frame Shift Del (DEL) | VAF 16/74 reads (22%) | called by mutect2, pindel, varscan2
- AMER1 | c.519del p.F173Lfs*36 | Frame Shift Del (DEL) | VAF 17/116 reads (15%) | called by mutect2, pindel, varscan2
- ANKRD34A | c.1280dup p.L428Sfs*11 | Frame Shift Ins (INS) | VAF 5/31 reads (16%) | called by mutect2, pindel
- ARHGEF9 | c.1021_1023del p.F341del | In Frame Del (DEL) | VAF 8/50 reads (16%) | called by pindel, varscan2
- ARID1A | c.3344del p.P1115Qfs*46 | Frame Shift Del (DEL) | VAF 7/68 reads (10%) | called by mutect2, pindel, varscan2
- ASPM | c.7857del p.K2619Nfs*22 | Frame Shift Del (DEL) | VAF 4/19 reads (21%) | called by pindel, varscan2
- ATXN7 | c.2216_2217del p.V739Gfs*16 | Frame Shift Del (DEL) | VAF 14/96 reads (15%) | called by pindel, varscan2
- B2M | c.43_44del p.L15Ffs*41 | Frame Shift Del (DEL) | VAF 15/86 reads (17%) | called by pindel, varscan2
- B3GNT5 | c.94del p.W32Gfs*9 | Frame Shift Del (DEL) | VAF 14/120 reads (12%) | called by mutect2, pindel, varscan2
- BAZ1A | c.219del p.A74Qfs*12 | Frame Shift Del (DEL) | VAF 24/138 reads (17%) | called by mutect2, varscan2
- BTAF1 | c.3437del p.L1146Wfs*27 | Frame Shift Del (DEL) | VAF 9/58 reads (16%) | called by mutect2, pindel, varscan2
- CACNG7 | c.513del p.H172Ifs*23 | Frame Shift Del (DEL) | VAF 24/162 reads (15%) | called by mutect2, pindel, varscan2
- CCDC88A | c.1189-2del p.X397_splice | Splice Site (DEL) | VAF 5/19 reads (26%) | called by mutect2, pindel, varscan2
- CD2BP2 | c.974del p.P325Lfs*58 | Frame Shift Del (DEL) | VAF 8/77 reads (10%) | called by mutect2, pindel, varscan2
- CDC16 | c.1670del p.N557Tfs*14 | Frame Shift Del (DEL) | VAF 15/54 reads (28%) | called by mutect2, pindel, varscan2
- CDYL | c.488del p.N163Tfs*27 (on ENST00000328908 / NM_001368125.1; = p.N109Tfs*27 on NM_004824.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 17/105 reads (16%) | called by mutect2, pindel, varscan2
- CEP57 | c.1420del p.R474Gfs*8 | Frame Shift Del (DEL) | VAF 8/43 reads (19%) | called by mutect2, pindel, varscan2
- CFAP47 | c.5178dup p.I1727Hfs*21 | Frame Shift Ins (INS) | VAF 10/71 reads (14%) | called by mutect2, pindel, varscan2
- CFAP91 | c.1623del p.A542Pfs*5 | Frame Shift Del (DEL) | VAF 7/69 reads (10%) | called by mutect2, pindel
- CIB3 | c.351dup p.N118* | Frame Shift Ins (INS) | VAF 16/124 reads (13%) | called by mutect2, pindel, varscan2
- CMAS | c.703del p.M235Wfs*14 | Frame Shift Del (DEL) | VAF 11/61 reads (18%) | called by mutect2, pindel, varscan2
- CPA5 | c.1101dup p.G368Wfs*20 | Frame Shift Ins (INS) | VAF 20/73 reads (27%) | called by mutect2, pindel, varscan2
- CPXM2 | c.1948_1949del p.D650Ffs*17 | Frame Shift Del (DEL) | VAF 19/128 reads (15%) | called by pindel, varscan2
- CRYGD | c.477del p.T160Rfs*8 | Frame Shift Del (DEL) | VAF 10/71 reads (14%) | called by mutect2, pindel, varscan2
- CTNNAL1 | c.179del p.K60Sfs*12 | Frame Shift Del (DEL) | VAF 17/111 reads (15%) | called by mutect2, pindel, varscan2
- CUL1 | c.1014dup p.L339Tfs*8 | Frame Shift Ins (INS) | VAF 7/57 reads (12%) | called by mutect2, pindel, varscan2
- CYBRD1 | c.*2del | Frame Shift Del (DEL) | VAF 5/52 reads (10%) | called by mutect2, pindel, varscan2
- DAPK1 | c.3822del p.Y1275Tfs*31 | Frame Shift Del (DEL) | VAF 8/82 reads (10%) | called by mutect2, pindel
- DLG5 | c.1128del p.F376Lfs*8 | Frame Shift Del (DEL) | VAF 19/118 reads (16%) | called by mutect2, pindel, varscan2
- DNAH5 | c.11029-2del p.X3677_splice | Splice Site (DEL) | VAF 5/14 reads (36%) | called by mutect2, varscan2
- DST | c.13858del p.L4620Wfs*8 (on ENST00000361203 / NM_001374722.1; = p.L2208Wfs*8 on NM_015548.5) | Frame Shift Del (DEL) | VAF 5/37 reads (14%) | called by mutect2, pindel
- DYNC1I1 | c.615dup p.Q206Tfs*30 | Frame Shift Ins (INS) | VAF 6/32 reads (19%) | called by mutect2, pindel
- ENPP3 | c.1992_1995del p.L665Gfs*18 | Frame Shift Del (DEL) | VAF 10/84 reads (12%) | called by mutect2, pindel
- EPB41L3 | c.2289del p.V764Cfs*12 | Frame Shift Del (DEL) | VAF 18/102 reads (18%) | called by mutect2, pindel, varscan2
- EPN1 | c.1367del p.P456Hfs*33 (on ENST00000270460 / NM_001321263.1; = p.P430Hfs*33 on NM_013333.3) | Frame Shift Del (DEL) | VAF 4/24 reads (17%) | called by mutect2, pindel
- ERICH3 | c.1276_1278del p.K426del | In Frame Del (DEL) | VAF 20/124 reads (16%) | called by pindel, varscan2
- FHDC1 | c.304del p.W102Gfs*55 | Frame Shift Del (DEL) | VAF 27/147 reads (18%) | called by mutect2, pindel, varscan2
338 further variants in this file (84 protein-altering or splice-affecting, 229 silent, 25 other) are not listed here.
